Somatic mutation profile of cancer-model specimen HCM-WCMC-1285-C54-85A (3D Organoid; aliquot HCM-WCMC-1285-C54-85A-01D-A937-36), derived from the primary tumor of HCMI case HCM-WCMC-1285-C54, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IIIC2; Tumor grade: G2; Age at diagnosis: 34.0 years (12,423 days).
Specimen HCM-WCMC-1285-C54-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 90135b3a-7768-4655-88ab-b3b68a265eef.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-WCMC-1285-C54-10A (Blood Derived Normal), aliquot HCM-WCMC-1285-C54-10A-01D-A937-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/581dc1f1-245c-44d2-a325-37597f754335

The open-access MAF lists 1,552 somatic variants for this specimen: 1,118 protein-altering or splice-affecting, 377 silent, 57 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 829, Silent 377, Frame Shift Del 156, Nonsense Mutation 58, Frame Shift Ins 48, Intron 30, In Frame Del 10, Splice Region 9, 3'Flank 8, Splice Site 8, 5'Flank 7, 3'UTR 5.

Variants (750 of 1,552; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA4 | c.6230G>A p.R2077Q | Missense Mutation (SNP) | VAF 163/379 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs886044759, CM1311152; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- CHST3 | c.533del p.G178Afs*38 | Frame Shift Del (DEL) | VAF 259/636 reads (41%) | catalogued as rs769540174; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- DNAH11 | c.13069C>T p.R4357* | Nonsense Mutation (SNP) | VAF 111/278 reads (40%) | catalogued as rs775720394, COSV60978335; ClinVar: pathogenic; called by muse, mutect2, varscan2
- FLNB | c.1592del p.G531Dfs*42 | Frame Shift Del (DEL) | VAF 47/289 reads (16%) | catalogued as rs746105983; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- KMT2D | c.13884del p.T4629Pfs*11 | Frame Shift Del (DEL) | VAF 104/205 reads (51%) | catalogued as rs886040960; ClinVar: pathogenic; called by mutect2, varscan2
- LIG4 | c.2321T>C p.L774P | Missense Mutation (SNP) | VAF 94/330 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1060499662; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- MAP2K1 | c.157T>G p.F53V | Missense Mutation (SNP) | VAF 178/352 reads (51%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as rs1057519728, COSV61068605, COSV61070825, COSV61071840; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- MYO7A | c.5617C>T p.R1873W | Missense Mutation (SNP) | VAF 144/314 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs397516321, CM064133; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- NIPBL | c.5167C>T p.R1723* | Nonsense Mutation (SNP) | VAF 152/341 reads (45%) | catalogued as rs121918267, CM042514, COSV56952714; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PAX2 | c.76del p.V26Cfs*3 | Frame Shift Del (DEL) | VAF 232/460 reads (50%) | catalogued as rs75462234, COSV62291007; ClinVar: pathogenic; called by mutect2, varscan2
- PIGO | c.2361del p.T788Lfs*25 | Frame Shift Del (DEL) | VAF 204/500 reads (41%) | catalogued as rs770591449, COSV99956719; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- PIK3R2 | c.1681A>G p.N561D | Missense Mutation (SNP) | VAF 220/412 reads (53%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as rs1057519801, COSV55847533; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PTEN | c.697C>T p.R233* | Nonsense Mutation (SNP) | VAF 328/329 reads (100%) | hotspot (GDC flag); catalogued as rs121909219, CM971277, COSV64288653, COSV64291717, COSV64302607, COSV64306399, COSV64306519, COSV64311585, COSV99058021; ClinVar: pathogenic / not provided; called by muse, mutect2, varscan2
- RNF43 | c.1111C>T p.R371* | Nonsense Mutation (SNP) | VAF 281/557 reads (50%) | hotspot (GDC flag); catalogued as rs771831816, COSV68457398; called by muse, mutect2, varscan2
- ABCC10 | c.1013C>T p.A338V (on ENST00000372530 / NM_001198934.2; = p.A295V on NM_033450.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 120/730 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs768546118; called by muse, varscan2
- ABCC6 | c.3312del p.Y1105Mfs*8 | Frame Shift Del (DEL) | VAF 135/349 reads (39%) | catalogued as COSV99229570; called by mutect2, pindel, varscan2
- ABCC8 | c.3293G>A p.R1098H | Missense Mutation (SNP) | VAF 181/379 reads (48%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1057523131; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ABI3BP | c.2246C>T p.P749L | Missense Mutation (SNP) | VAF 125/277 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.013); catalogued as COSV99428732; called by muse, mutect2, varscan2
- AC004593.2 | c.1120C>T p.R374W | Missense Mutation (SNP) | VAF 107/253 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs759575449; called by muse, mutect2, varscan2
- AC008397.2 | c.1891C>T p.R631* | Nonsense Mutation (SNP) | VAF 204/408 reads (50%) | catalogued as rs780245468; called by muse, mutect2, varscan2
- ACACB | c.1495C>T p.R499C | Missense Mutation (SNP) | VAF 174/364 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs978164597, COSV100622284; called by muse, varscan2
- ACSL1 | c.220G>A p.A74T | Missense Mutation (SNP) | VAF 135/284 reads (48%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as rs762658676, COSV55663671; called by muse, mutect2, varscan2
- ACTR5 | c.934C>T p.R312W | Missense Mutation (SNP) | VAF 202/456 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs772935923, COSV54762280; called by muse, mutect2, varscan2
- ACVR1 | c.1124G>A p.R375H | Missense Mutation (SNP) | VAF 360/566 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as CM091422, COSV99717598; called by muse, mutect2, varscan2
- ADAM8 | c.128G>A p.R43H | Missense Mutation (SNP) | VAF 114/426 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.567); catalogued as rs376018925, COSV53308344; called by muse, mutect2, varscan2
- ADAMTS12 | c.4070C>T p.A1357V | Missense Mutation (SNP) | VAF 153/338 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.885); catalogued as COSV61270540, COSV61286757; called by muse, mutect2, varscan2
- ADAMTS18 | c.3280C>T p.R1094* | Nonsense Mutation (SNP) | VAF 148/316 reads (47%) | catalogued as rs775431905, COSV51417329; called by muse, mutect2, varscan2
- ADAMTSL1 | c.1633C>T p.R545* | Nonsense Mutation (SNP) | VAF 184/388 reads (47%) | catalogued as rs761956033, COSV52815302; called by muse, mutect2, varscan2
- ADAMTSL1 | c.4123del p.Q1375Kfs*24 | Frame Shift Del (DEL) | VAF 123/262 reads (47%) | catalogued as COSV65879385; called by mutect2, varscan2
- ADGRB1 | c.1780A>G p.T594A | Missense Mutation (SNP) | VAF 154/344 reads (45%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.998); catalogued as COSV100029476; called by muse, mutect2, varscan2
- ADGRG7 | c.1989del p.V664Ffs*4 | Frame Shift Del (DEL) | VAF 56/140 reads (40%) | catalogued as rs746519567; called by mutect2, varscan2
- ADSS1 | c.863del p.P288Rfs*4 | Frame Shift Del (DEL) | VAF 208/461 reads (45%) | catalogued as rs1566801565, COSV58275931; called by mutect2, pindel, varscan2
- AFF2 | c.2936C>T p.A979V | Missense Mutation (SNP) | VAF 120/121 reads (99%) | SIFT tolerated (0.46); PolyPhen benign (0.062); catalogued as rs146808155, COSV54000593; called by muse, mutect2, varscan2
- AFF4 | c.2540G>A p.S847N | Missense Mutation (SNP) | VAF 22/486 reads (5%) | SIFT tolerated (0.41); PolyPhen benign (0.001); catalogued as rs779909037; called by muse, mutect2
- AGO2 | c.1806dup p.A603Rfs*71 | Frame Shift Ins (INS) | VAF 188/411 reads (46%) | catalogued as rs748399150; called by mutect2, varscan2
- AHCY | c.400G>A p.D134N | Missense Mutation (SNP) | VAF 188/413 reads (46%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.506); catalogued as rs1021875336; called by muse, mutect2, varscan2
- AKNA | c.2375del p.G792Efs*49 | Frame Shift Del (DEL) | VAF 250/589 reads (42%) | catalogued as COSV99034379; called by mutect2, pindel, varscan2
- AL121899.2 | c.260C>T p.A87V | Missense Mutation (SNP) | VAF 118/282 reads (42%) | SIFT tolerated (0.5); PolyPhen benign (0.005); catalogued as rs1368754825; called by muse, mutect2, varscan2
- ALPP | c.1489G>A p.D497N | Missense Mutation (SNP) | VAF 300/671 reads (45%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as COSV67396129; called by muse, mutect2, varscan2
- ANKK1 | c.2059G>A p.A687T | Missense Mutation (SNP) | VAF 213/429 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0.081); catalogued as rs768579058, COSV58274158; called by muse, mutect2, varscan2
- ANKRD11 | c.6704C>T p.P2235L | Missense Mutation (SNP) | VAF 270/527 reads (51%) | SIFT tolerated, low confidence (0.76); PolyPhen benign (0); catalogued as rs1394383095, COSV56359939, COSV56370923; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ANKRD18A | c.844del p.R282Efs*11 | Frame Shift Del (DEL) | VAF 57/166 reads (34%) | catalogued as rs1563970981; called by mutect2, pindel, varscan2
- ANKRD30A | c.584del p.N195Mfs*26 (on ENST00000611781; = p.N139Mfs*26 on NM_052997.2) | Frame Shift Del (DEL) | VAF 105/248 reads (42%) | catalogued as COSV64613285; called by mutect2, pindel, varscan2
- ANKRD30A | c.1802C>A p.S601Y (on ENST00000611781; = p.S545Y on NM_052997.2) | Missense Mutation (SNP) | VAF 56/126 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as COSV64609660; called by muse, mutect2, varscan2
- ANKRD34B | c.206A>G p.Y69C | Missense Mutation (SNP) | VAF 59/387 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100103469; called by muse, mutect2, varscan2
- AP002748.5 | c.125A>G p.H42R | Missense Mutation (SNP) | VAF 70/419 reads (17%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.006); catalogued as rs201819981; called by muse, mutect2, varscan2
- ARFGAP1 | c.1150G>A p.G384R | Missense Mutation (SNP) | VAF 269/537 reads (50%) | SIFT tolerated, low confidence (0.25); PolyPhen probably damaging (1); catalogued as rs1008965738; called by muse, mutect2, varscan2
- ARHGEF40 | c.2726G>A p.R909Q | Missense Mutation (SNP) | VAF 284/590 reads (48%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.46); catalogued as rs373963892; called by muse, mutect2, varscan2
- ARID1A | c.4052G>A p.G1351D | Missense Mutation (SNP) | VAF 136/300 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.441); catalogued as COSV100249873; called by muse, mutect2, varscan2
- ARID1A | c.4534C>T p.Q1512* | Nonsense Mutation (SNP) | VAF 240/438 reads (55%) | catalogued as COSV61373983; called by muse, varscan2
- ATF6B | c.1898G>A p.R633H | Missense Mutation (SNP) | VAF 225/714 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.198); catalogued as rs753618773; called by muse, mutect2, varscan2
- ATG4D | c.1015C>T p.R339* | Nonsense Mutation (SNP) | VAF 156/363 reads (43%) | catalogued as rs142082988; called by muse, mutect2, varscan2
- ATP1B2 | c.136G>A p.V46I | Missense Mutation (SNP) | VAF 107/257 reads (42%) | SIFT tolerated (0.27); PolyPhen benign (0.017); catalogued as rs372597402; called by muse, mutect2, varscan2
- ATP5MG | c.268G>A p.G90R | Missense Mutation (SNP) | VAF 83/201 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.449); catalogued as rs200472961; called by muse, mutect2, varscan2
- ATP6V0C | c.364G>A p.A122T | Missense Mutation (SNP) | VAF 274/534 reads (51%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.983); catalogued as rs1321416008; called by muse, mutect2, varscan2
- ATXN10 | c.922G>A p.D308N | Missense Mutation (SNP) | VAF 164/331 reads (50%) | SIFT deleterious (0.03); PolyPhen benign (0.231); catalogued as rs1042452273, COSV53298989, COSV99426550; called by muse, mutect2, varscan2
- AUTS2 | c.3086C>T p.T1029M | Missense Mutation (SNP) | VAF 267/573 reads (47%) | SIFT deleterious (0.03); PolyPhen benign (0.36); catalogued as rs755394081; called by muse, mutect2, varscan2
- AVPI1 | c.80C>T p.S27L | Missense Mutation (SNP) | VAF 268/545 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.253); catalogued as rs112461058, COSV65697587; called by muse, mutect2, varscan2
- AXL | c.874del p.H292Ifs*5 | Frame Shift Del (DEL) | VAF 240/619 reads (39%) | catalogued as rs778012871; called by pindel, varscan2
- B2M | c.45_48del p.S16Afs*27 | Frame Shift Del (DEL) | VAF 175/358 reads (49%) | catalogued as COSV62562863; called by mutect2, pindel, varscan2
- B3GNT3 | c.650C>G p.T217R | Missense Mutation (SNP) | VAF 168/365 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57952871; called by muse, mutect2, varscan2
- B4GALT3 | c.539G>A p.R180Q | Missense Mutation (SNP) | VAF 191/422 reads (45%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.781); catalogued as rs756962425, COSV60526693; called by muse, mutect2, varscan2
- BACH1 | c.139G>A p.A47T | Missense Mutation (SNP) | VAF 188/380 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1250115670; called by muse, varscan2
- BAIAP2 | c.1027G>A p.V343M | Missense Mutation (SNP) | VAF 92/485 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.121); catalogued as rs778465491, COSV100347346; called by muse, mutect2, varscan2
- BBS9 | c.1561C>T p.R521* (on ENST00000242067 / NM_001348036.1; = p.R481* on NM_014451.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 112/255 reads (44%) | catalogued as rs748601675, COSV54157359; called by muse, mutect2, varscan2
- BCKDK | c.47C>T p.P16L | Missense Mutation (SNP) | VAF 212/415 reads (51%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0); catalogued as rs749467687; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BCL6 | c.1913G>A p.R638H | Missense Mutation (SNP) | VAF 185/374 reads (49%) | SIFT tolerated (0.49); PolyPhen probably damaging (0.997); catalogued as rs1468858377, COSV51653748; called by muse, mutect2, varscan2
- BCL7C | c.617del p.P206Hfs*36 | Frame Shift Del (DEL) | VAF 191/451 reads (42%) | catalogued as rs754078059; called by mutect2, pindel, varscan2
- BCORL1 | c.1929del p.M644Cfs*4 | Frame Shift Del (DEL) | VAF 287/402 reads (71%) | catalogued as rs1229639561; called by mutect2, pindel, varscan2
- BIRC6 | c.8708C>T p.P2903L | Missense Mutation (SNP) | VAF 212/641 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs192943089; called by muse, mutect2, varscan2
- BIRC6 | c.10810G>A p.A3604T | Missense Mutation (SNP) | VAF 156/422 reads (37%) | SIFT tolerated (0.65); PolyPhen benign (0.006); catalogued as rs369960712, COSV70204867; called by muse, mutect2, varscan2
- BMP8B | c.880G>A p.G294S | Missense Mutation (SNP) | VAF 150/460 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.048); catalogued as rs137876639; called by muse, varscan2
- BPIFB1 | c.1117C>T p.R373C | Missense Mutation (SNP) | VAF 152/342 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.11); catalogued as rs1340556429; called by muse, mutect2, varscan2
- BRF1 | c.1378-6G>A | Splice Region (SNP) | VAF 220/469 reads (47%) | catalogued as rs587682422, COSV59266325; called by muse, mutect2, varscan2
- BRPF3 | c.43C>T p.R15W | Missense Mutation (SNP) | VAF 175/605 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.333); catalogued as rs371915331; called by muse, mutect2, varscan2
- BRWD1 | c.3919del p.S1307Afs*19 | Frame Shift Del (DEL) | VAF 118/288 reads (41%) | catalogued as rs1296036169; called by mutect2, pindel, varscan2
- C10orf120 | c.556A>G p.I186V | Missense Mutation (SNP) | VAF 211/432 reads (49%) | SIFT tolerated (0.41); PolyPhen benign (0.006); catalogued as rs1240570346; called by muse, mutect2, varscan2
- C14orf132 | c.251G>A p.R84Q (on ENST00000553782 / NM_001289139.2; = p.R53Q on NM_001252507.3) | Missense Mutation (SNP) | VAF 224/454 reads (49%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.996); catalogued as rs1188567084; called by muse, varscan2
- C19orf67 | c.194C>T p.T65M | Missense Mutation (SNP) | VAF 251/543 reads (46%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as rs553160046; called by muse, mutect2, varscan2
- C1QTNF6 | c.618del p.Y206* | Frame Shift Del (DEL) | VAF 223/514 reads (43%) | catalogued as COSV99742368; called by mutect2, pindel, varscan2
- C20orf194 | c.2137G>A p.A713T | Missense Mutation (SNP) | VAF 139/280 reads (50%) | SIFT tolerated (0.57); PolyPhen benign (0.001); catalogued as rs374809056; called by muse, mutect2, varscan2
- C3 | c.4594C>T p.R1532W | Missense Mutation (SNP) | VAF 156/295 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs199911426; called by muse, mutect2, varscan2
- C6orf15 | c.559G>A p.G187R | Missense Mutation (SNP) | VAF 398/1092 reads (36%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs756329609, COSV52539684; called by muse, mutect2, varscan2
- C8orf82 | c.430C>T p.R144C | Missense Mutation (SNP) | VAF 270/528 reads (51%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.901); catalogued as COSV52766720; called by muse, varscan2
- CACNA1B | c.4412C>T p.P1471L | Missense Mutation (SNP) | VAF 222/413 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as rs200167577, COSV53142521, COSV99495922; called by muse, mutect2, varscan2
- CACNA1F | c.1355G>A p.R452H | Missense Mutation (SNP) | VAF 223/223 reads (100%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs1234852260; called by muse, mutect2, varscan2
- CACNA1G | c.4160G>A p.R1387H | Missense Mutation (SNP) | VAF 84/186 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1174908448, COSV61732475; called by muse, varscan2
- CACNA1S | c.1889C>T p.P630L | Missense Mutation (SNP) | VAF 166/394 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs150646872; called by muse, mutect2, varscan2
- CARD9 | c.263C>T p.P88L | Missense Mutation (SNP) | VAF 210/456 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs141691778, COSV53733594; called by muse, mutect2, varscan2
- CASKIN1 | c.2480C>T p.P827L | Missense Mutation (SNP) | VAF 392/745 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1471502766; called by muse, mutect2, varscan2
- CASKIN2 | c.1472C>T p.A491V | Missense Mutation (SNP) | VAF 118/263 reads (45%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.985); catalogued as rs374772637; called by muse, mutect2, varscan2
- CASP8 | c.1294C>T p.R432* (on ENST00000432109 / NM_033355.3; = p.R449* on NM_001228.4) | Nonsense Mutation (SNP) | VAF 106/208 reads (51%) | catalogued as rs931648756, COSV51845077; called by muse, mutect2, varscan2
- CAVIN2 | c.1210G>A p.E404K | Missense Mutation (SNP) | VAF 169/334 reads (51%) | SIFT tolerated, low confidence (0.83); PolyPhen benign (0.007); catalogued as rs766866506, COSV58423322; called by muse, mutect2, varscan2
- CBX6 | c.249G>A p.A83= | Splice Region (SNP) | VAF 31/167 reads (19%) | catalogued as rs1306720853; called by muse, mutect2, varscan2
- CCAR1 | c.1147C>T p.R383C | Missense Mutation (SNP) | VAF 113/248 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs757298807; called by muse, mutect2, varscan2
- CCAR1 | c.2140C>T p.R714C | Missense Mutation (SNP) | VAF 116/240 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.312); catalogued as rs759599293; called by muse, varscan2
- CCDC114 | c.1528G>A p.A510T | Missense Mutation (SNP) | VAF 97/450 reads (22%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as rs761311942; called by muse, mutect2, varscan2
- CCDC116 | c.994G>A p.G332S | Missense Mutation (SNP) | VAF 247/515 reads (48%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs201583912; called by muse, mutect2, varscan2
- CCDC146 | c.939G>T p.K313N | Missense Mutation (SNP) | VAF 152/328 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as rs909346926; called by muse, mutect2, varscan2
- CCDC184 | c.209C>T p.S70L | Missense Mutation (SNP) | VAF 259/493 reads (53%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as COSV57251823; called by muse, mutect2, varscan2
- CCDC51 | c.887T>C p.V296A | Missense Mutation (SNP) | VAF 204/401 reads (51%) | SIFT tolerated (0.46); PolyPhen benign (0.003); catalogued as rs553082516; called by muse, mutect2, varscan2
- CCDC87 | c.1441dup p.M481Nfs*4 | Frame Shift Ins (INS) | VAF 201/507 reads (40%) | catalogued as rs1251984014; called by mutect2, pindel, varscan2
- CCER1 | c.493G>A p.D165N | Missense Mutation (SNP) | VAF 320/635 reads (50%) | SIFT deleterious (0.05); PolyPhen benign (0.043); catalogued as rs1412453346; called by muse, mutect2, varscan2
- CD2 | c.908G>A p.R303H | Missense Mutation (SNP) | VAF 228/484 reads (47%) | SIFT tolerated (0.12); PolyPhen benign (0.075); catalogued as rs748882774, COSV65644050; called by muse, varscan2
- CD300LG | c.651dup p.M218Hfs*21 | Frame Shift Ins (INS) | VAF 159/376 reads (42%) | catalogued as rs760923345; called by mutect2, varscan2
- CDH23 | c.3251G>A p.G1084D | Missense Mutation (SNP) | VAF 184/379 reads (49%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.84); catalogued as rs754122678; called by muse, mutect2, varscan2
- CDHR2 | c.1139C>T p.A380V | Missense Mutation (SNP) | VAF 181/371 reads (49%) | SIFT tolerated (0.06); PolyPhen benign (0.005); catalogued as rs745537051; called by muse, mutect2, varscan2
- CENPB | c.871C>T p.R291W | Missense Mutation (SNP) | VAF 269/542 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1372115231, COSV60150573; called by muse, mutect2, varscan2
- CENPN | c.461A>G p.Y154C | Missense Mutation (SNP) | VAF 157/337 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100001136; called by muse, varscan2
- CEP120 | c.1645G>A p.A549T | Missense Mutation (SNP) | VAF 182/373 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as COSV60265780; called by muse, mutect2, varscan2
- CES4A | c.1372G>A p.V458I (on ENST00000648724 / NM_001364782.1; = p.V360I on NM_001190201.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 161/361 reads (45%) | SIFT tolerated (0.92); PolyPhen benign (0.006); catalogued as rs1038431195, COSV58651594; called by muse, mutect2, varscan2
- CFAP54 | c.4253del p.K1418Rfs*4 | Frame Shift Del (DEL) | VAF 85/152 reads (56%) | catalogued as rs1274191949; called by mutect2, varscan2
- CFAP61 | c.749T>C p.M250T | Missense Mutation (SNP) | VAF 39/410 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.048); catalogued as rs941692690; called by muse, mutect2
- CFH | c.1926G>T p.K642N | Missense Mutation (SNP) | VAF 162/343 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.22); catalogued as COSV66410353; called by muse, mutect2, varscan2
- CHD4 | c.3445C>T p.R1149W (on ENST00000357008 / NM_001363606.2; = p.R1162W on NM_001273.5) | Missense Mutation (SNP) | VAF 191/293 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58894467; called by muse, mutect2, varscan2
- CHRNB3 | c.616G>A p.A206T | Missense Mutation (SNP) | VAF 171/390 reads (44%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs576780909, COSV51494948; called by muse, mutect2, varscan2
- CIC | c.1352G>A p.G451D | Missense Mutation (SNP) | VAF 272/514 reads (53%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.956); catalogued as COSV73907326; called by muse, mutect2, varscan2
- CKAP5 | c.5387G>A p.R1796Q (on ENST00000529230 / NM_001008938.4; = p.R1736Q on NM_014756.3) | Missense Mutation (SNP) | VAF 155/327 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.665); catalogued as rs758663989; called by muse, mutect2, varscan2
- CLCNKA | c.1901C>T p.T634M | Missense Mutation (SNP) | VAF 132/267 reads (49%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.851); catalogued as rs200446764; called by muse, mutect2, varscan2
- CLOCK | c.368del p.L123* | Frame Shift Del (DEL) | VAF 77/180 reads (43%) | catalogued as rs369752219; called by mutect2, varscan2
- CLUH | c.305C>T p.S102L (on ENST00000435359; = p.S140L on NM_015229.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 239/436 reads (55%) | SIFT deleterious (0); PolyPhen benign (0.048); catalogued as rs748184428; called by muse, mutect2, varscan2
- CNGB1 | c.2758T>C p.W920R | Missense Mutation (SNP) | VAF 69/296 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs867003183; called by muse, mutect2, varscan2
- CNGB1 | c.803C>T p.P268L | Missense Mutation (SNP) | VAF 148/289 reads (51%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs369288085; called by muse, mutect2, varscan2
- CNTNAP5 | c.1369G>A p.A457T | Missense Mutation (SNP) | VAF 161/499 reads (32%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.764); catalogued as rs779684862; called by muse, mutect2, varscan2
- CNTNAP5 | c.2374G>A p.A792T | Missense Mutation (SNP) | VAF 184/279 reads (66%) | SIFT deleterious (0.02); PolyPhen benign (0.349); catalogued as rs1425252476, COSV70487458; called by muse, mutect2, varscan2
- COL22A1 | c.7G>A p.G3S | Missense Mutation (SNP) | VAF 127/303 reads (42%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0); catalogued as rs769944178; called by muse, mutect2, varscan2
- COL25A1 | c.1090C>T p.R364W | Missense Mutation (SNP) | VAF 166/337 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs960016417, COSV67651331; called by muse, mutect2, varscan2
- COL2A1 | c.3137del p.P1046Lfs*84 | Frame Shift Del (DEL) | VAF 164/413 reads (40%) | catalogued as CD063500; called by mutect2, pindel, varscan2
- COL6A1 | c.1694G>A p.R565Q | Missense Mutation (SNP) | VAF 185/412 reads (45%) | SIFT tolerated (0.57); PolyPhen benign (0.001); catalogued as rs886057155; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL8A2 | c.668del p.G223Vfs*14 | Frame Shift Del (DEL) | VAF 215/510 reads (42%) | catalogued as COSV57443421; called by mutect2, pindel, varscan2
- COPA | c.1268G>A p.R423Q | Missense Mutation (SNP) | VAF 123/257 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1385335743, COSV54104948; called by muse, mutect2, varscan2
- CORO6 | c.206G>A p.R69Q | Missense Mutation (SNP) | VAF 109/229 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); catalogued as rs1242132064, COSV100801156; called by muse, mutect2, varscan2
- CP | c.2122G>A p.G708S | Missense Mutation (SNP) | VAF 168/338 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1056623509, CM148239, COSV52834538; called by muse, mutect2, varscan2
- CPA2 | c.283G>A p.V95M | Missense Mutation (SNP) | VAF 117/250 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.959); catalogued as rs751540588, COSV55980371; called by muse, mutect2, varscan2
- CRMP1 | c.1675G>A p.V559M | Missense Mutation (SNP) | VAF 87/430 reads (20%) | SIFT tolerated (0.29); PolyPhen benign (0.085); catalogued as COSV100271440, COSV61478773; called by muse, mutect2, varscan2
- CSMD1 | c.5293C>T p.R1765* (on ENST00000520002; = p.R1764* on NM_033225.6) | Nonsense Mutation (SNP) | VAF 182/356 reads (51%) | catalogued as COSV59298786; called by muse, mutect2, varscan2
- CSMD2 | c.4801G>T p.G1601W | Missense Mutation (SNP) | VAF 213/455 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53934422; called by muse, mutect2, varscan2
- CSPP1 | c.3268A>G p.R1090G (on ENST00000676605; = p.R1049G on NM_024790.6) | Missense Mutation (SNP) | VAF 96/206 reads (47%) | SIFT tolerated (0.1); PolyPhen benign (0.299); catalogued as COSV51580488; called by muse, varscan2
- CTBP2 | c.530G>A p.R177H | Missense Mutation (SNP) | VAF 197/383 reads (51%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.962); catalogued as rs1194942389, COSV58338413; called by muse, mutect2, varscan2
- CXXC5 | c.467C>T p.A156V | Missense Mutation (SNP) | VAF 272/520 reads (52%) | SIFT tolerated (0.25); PolyPhen benign (0.182); catalogued as COSV56795125; called by muse, mutect2, varscan2
- CYP2A13 | c.1021C>T p.P341S | Missense Mutation (SNP) | VAF 237/482 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV57836938; called by muse, mutect2, varscan2
- CYP4F12 | c.1543C>T p.R515W | Missense Mutation (SNP) | VAF 89/204 reads (44%) | SIFT tolerated (0.06); PolyPhen benign (0.204); catalogued as rs1045250790, COSV61173169; called by muse, mutect2, varscan2
- DAB2IP | c.1768C>T p.R590C (on ENST00000408936; = p.R562C on NM_032552.3) | Missense Mutation (SNP) | VAF 208/410 reads (51%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.68); catalogued as rs766959002, COSV52257062; called by muse, varscan2
- DCHS2 | c.1420G>A p.G474R | Missense Mutation (SNP) | VAF 231/498 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs1302134798, COSV59727308; called by muse, mutect2, varscan2
- DCHS2 | c.812G>A p.G271D | Missense Mutation (SNP) | VAF 243/516 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs909564541; called by muse, mutect2, varscan2
- DDX5 | c.1018_1020del p.K340del | In Frame Del (DEL) | VAF 86/214 reads (40%) | catalogued as rs1555671300; called by mutect2, pindel, varscan2
- DENND1A | c.2299C>T p.P767S | Missense Mutation (SNP) | VAF 142/554 reads (26%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.03); catalogued as COSV65357729; called by muse, mutect2, varscan2
- DGKD | c.1370G>A p.R457Q (on ENST00000264057 / NM_152879.3; = p.R413Q on NM_003648.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 181/507 reads (36%) | SIFT tolerated (0.29); PolyPhen benign (0.018); catalogued as rs866444573; called by muse, mutect2, varscan2
- DGKD | c.2276C>T p.T759M (on ENST00000264057 / NM_152879.3; = p.T715M on NM_003648.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 202/305 reads (66%) | SIFT tolerated (0.19); PolyPhen benign (0.029); catalogued as rs376456548, COSV51037705; called by muse, mutect2, varscan2
- DIAPH1 | c.2108del p.P703Hfs*65 | Frame Shift Del (DEL) | VAF 92/173 reads (53%) | catalogued as rs771360300; called by mutect2, varscan2
- DIO2 | c.358C>T p.P120S | Missense Mutation (SNP) | VAF 194/375 reads (52%) | SIFT tolerated (0.52); PolyPhen benign (0.003); catalogued as rs1490426699; called by muse, mutect2, varscan2
- DIP2A | c.3778G>A p.A1260T | Missense Mutation (SNP) | VAF 137/288 reads (48%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as rs368502145; called by muse, mutect2, varscan2
- DLGAP1 | c.377C>T p.T126M | Missense Mutation (SNP) | VAF 294/560 reads (53%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.724); catalogued as rs200676669, COSV59796282; called by muse, mutect2, varscan2
- DLL1 | c.1504C>T p.R502C | Missense Mutation (SNP) | VAF 387/719 reads (54%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs2747761; called by muse, mutect2, varscan2
- DLL1 | c.1382G>A p.G461D | Missense Mutation (SNP) | VAF 306/676 reads (45%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.794); catalogued as rs1039024205; called by muse, mutect2, varscan2
- DNAH2 | c.7058C>T p.T2353M | Missense Mutation (SNP) | VAF 99/217 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs145304537; called by muse, mutect2, varscan2
- DNAH5 | c.233G>A p.R78Q | Missense Mutation (SNP) | VAF 134/301 reads (45%) | SIFT tolerated (0.13); PolyPhen benign (0.011); catalogued as rs755574532, COSV54233163; called by muse, mutect2, varscan2
- DNAJC16 | c.1680C>T p.S560= | Splice Region (SNP) | VAF 129/263 reads (49%) | catalogued as rs148700636; called by muse, mutect2, varscan2
- DNAJC16 | c.2169A>G p.I723M | Missense Mutation (SNP) | VAF 216/485 reads (45%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs778529647; called by muse, mutect2, varscan2
- DNAJC5 | c.188C>T p.A63V | Missense Mutation (SNP) | VAF 174/399 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs139312819; ClinVar: uncertain significance; called by muse, varscan2
- DNM1L | c.2191C>T p.R731W (on ENST00000549701 / NM_012062.5; = p.R694W on NM_005690.4) | Missense Mutation (SNP) | VAF 110/255 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs750745310; called by muse, mutect2, varscan2
- DNMT3A | c.306G>T p.E102D | Missense Mutation (SNP) | VAF 438/729 reads (60%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.636); catalogued as rs200559311; called by muse, mutect2, varscan2
- DNMT3A | c.98G>A p.R33H | Missense Mutation (SNP) | VAF 378/587 reads (64%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.132); catalogued as rs746009417, COSV53049060, COSV53053091; called by muse, mutect2, varscan2
- DNTT | c.170G>A p.R57H | Missense Mutation (SNP) | VAF 122/274 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs775903509, COSV100960775; called by muse, varscan2
- DOT1L | c.1768C>T p.R590C | Missense Mutation (SNP) | VAF 176/396 reads (44%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.564); catalogued as rs371142941; called by muse, mutect2, varscan2
- DUS1L | c.842C>T p.T281M | Missense Mutation (SNP) | VAF 168/326 reads (52%) | SIFT deleterious (0.02); PolyPhen benign (0.37); catalogued as rs778481501; called by muse, mutect2, varscan2
- DUS4L-BCAP29 | c.1493C>T p.S498L | Missense Mutation (SNP) | VAF 80/193 reads (41%) | SIFT tolerated, low confidence (0.64); PolyPhen benign (0.003); catalogued as rs267601226; called by muse, mutect2, varscan2
- DUSP8 | c.1847C>T p.S616L | Missense Mutation (SNP) | VAF 192/405 reads (47%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.559); catalogued as rs1202525328; called by muse, mutect2, varscan2
- DYNC2H1 | c.9020G>A p.R3007H | Missense Mutation (SNP) | VAF 171/369 reads (46%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.875); catalogued as rs1261435614, COSV62098513; called by muse, mutect2, varscan2
- ECE1 | c.694C>T p.R232C | Missense Mutation (SNP) | VAF 215/440 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); catalogued as rs1305763532, COSV51662368; called by muse, mutect2, varscan2
- EDNRB | c.718C>T p.H240Y (on ENST00000377211 / NM_001201397.1; = p.H150Y on NM_000115.5) | Missense Mutation (SNP) | VAF 134/282 reads (48%) | SIFT tolerated (0.55); PolyPhen benign (0.003); catalogued as COSV57525085; called by muse, mutect2, varscan2
- EFTUD2 | c.1876G>A p.E626K | Missense Mutation (SNP) | VAF 126/299 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs764767656, COSV68182081; called by muse, mutect2, varscan2
- EGLN3 | c.197C>T p.A66V | Missense Mutation (SNP) | VAF 280/543 reads (52%) | SIFT tolerated (0.14); PolyPhen benign (0.006); catalogued as COSV99164386; called by muse, mutect2, varscan2
- ELAVL2 | c.656A>G p.Y219C | Missense Mutation (SNP) | VAF 163/369 reads (44%) | SIFT tolerated (0.06); PolyPhen benign (0.005); catalogued as rs753913440; called by muse, mutect2, varscan2
- ELOVL7 | c.316C>T p.R106W | Missense Mutation (SNP) | VAF 105/229 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs749088345, COSV70917986; called by muse, mutect2, varscan2
- ENTPD6 | c.620C>T p.S207L | Missense Mutation (SNP) | VAF 111/245 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as rs747725682; called by muse, mutect2, varscan2
- ENTPD7 | c.1181A>G p.N394S | Missense Mutation (SNP) | VAF 209/416 reads (50%) | SIFT tolerated (0.22); PolyPhen benign (0.046); catalogued as rs1364988564; called by muse, mutect2, varscan2
- EPHB3 | c.83T>C p.L28P | Missense Mutation (SNP) | VAF 134/313 reads (43%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.766); catalogued as rs1429789406; called by muse, mutect2, varscan2
- ERF | c.896del p.G299Efs*12 | Frame Shift Del (DEL) | VAF 243/599 reads (41%) | catalogued as rs780487406; called by mutect2, pindel, varscan2
- ERGIC3 | c.80del p.G27Afs*4 | Frame Shift Del (DEL) | VAF 206/485 reads (42%) | catalogued as COSV54141087; called by mutect2, pindel, varscan2
- ERN2 | c.2263C>T p.R755W | Missense Mutation (SNP) | VAF 149/360 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as rs777486951, COSV55624999; called by muse, mutect2, varscan2
- ESRP1 | c.1535del p.N512Tfs*2 | Frame Shift Del (DEL) | VAF 308/313 reads (98%) | catalogued as rs775950025; called by mutect2, varscan2
- EXOSC2 | c.707G>A p.R236Q | Missense Mutation (SNP) | VAF 92/207 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs143707199; called by muse, mutect2, varscan2
- EXTL3 | c.2077G>A p.V693M | Missense Mutation (SNP) | VAF 205/435 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1018298399; called by muse, mutect2, varscan2
- FAAP100 | c.2030C>T p.A677V | Missense Mutation (SNP) | VAF 327/648 reads (50%) | SIFT deleterious (0.04); PolyPhen benign (0.065); catalogued as rs774743717; called by muse, mutect2, varscan2
- FAM120B | c.2222C>T p.A741V | Missense Mutation (SNP) | VAF 191/440 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs775606266, COSV99378764; called by muse, mutect2, varscan2
- FAM163B | c.458G>A p.R153Q | Missense Mutation (SNP) | VAF 223/477 reads (47%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.525); catalogued as rs780818543, COSV100618914; called by muse, varscan2
- FAM171B | c.2467A>T p.I823F | Missense Mutation (SNP) | VAF 123/254 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.238); catalogued as rs1304871872; called by muse, mutect2, varscan2
- FAM184A | c.1530+1G>A p.X510_splice | Splice Site (SNP) | VAF 84/186 reads (45%) | catalogued as rs545433444; called by muse, mutect2, varscan2
- FAM20A | c.1157C>T p.P386L | Missense Mutation (SNP) | VAF 129/255 reads (51%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.918); catalogued as rs764623015; called by muse, mutect2, varscan2
- FAM76A | c.233C>T p.A78V | Missense Mutation (SNP) | VAF 136/278 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.596); catalogued as rs773214874, COSV50548943; called by muse, mutect2, varscan2
- FAM83B | c.1069G>A p.G357R | Missense Mutation (SNP) | VAF 164/346 reads (47%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as rs376026026; called by muse, mutect2, varscan2
- FARP2 | c.353G>A p.R118H | Missense Mutation (SNP) | VAF 227/346 reads (66%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.987); catalogued as rs199738844; called by muse, mutect2, varscan2
- FBF1 | c.2870G>A p.R957Q (on ENST00000586717; = p.R972Q on NM_001319193.1) | Missense Mutation (SNP) | VAF 227/443 reads (51%) | SIFT tolerated (0.16); PolyPhen benign (0.03); catalogued as rs553617516; called by muse, mutect2, varscan2
- FBN2 | c.7204C>T p.R2402C | Missense Mutation (SNP) | VAF 185/376 reads (49%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.878); catalogued as rs916476326, COSV52505801, COSV52548116; called by muse, mutect2, varscan2
- FBXO43 | c.1896del p.F632Lfs*6 | Frame Shift Del (DEL) | VAF 123/284 reads (43%) | catalogued as rs34677327; called by mutect2, pindel, varscan2
- FGF11 | c.431G>A p.R144H | Missense Mutation (SNP) | VAF 105/197 reads (53%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.915); catalogued as rs530767669; called by muse, mutect2, varscan2
- FNBP4 | c.2863C>T p.R955C | Missense Mutation (SNP) | VAF 129/269 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs763833197; called by muse, mutect2, varscan2
- FNDC3A | c.2037A>G p.I679M (on ENST00000492622 / NM_001079673.2; = p.I623M on NM_014923.5) | Missense Mutation (SNP) | VAF 20/300 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.756); catalogued as COSV68134269; called by muse, mutect2
- FOXN3 | c.841C>T p.R281W (on ENST00000261302; = p.R259W on NM_005197.4) | Missense Mutation (SNP) | VAF 41/362 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs145640730; called by muse, mutect2, varscan2
- FRMPD3 | c.3039del p.S1014Afs*18 | Frame Shift Del (DEL) | VAF 273/389 reads (70%) | catalogued as rs752351689; called by mutect2, pindel, varscan2
- GABBR1 | c.1721dup p.A575Sfs*2 | Frame Shift Ins (INS) | VAF 153/502 reads (30%) | catalogued as rs777471402; called by mutect2, varscan2
- GABBR1 | c.344C>T p.T115M | Missense Mutation (SNP) | VAF 498/789 reads (63%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.286); catalogued as rs757008467, COSV63540730; called by muse, mutect2, varscan2
- GALNT5 | c.1970dup p.N657Kfs*4 | Frame Shift Ins (INS) | VAF 47/356 reads (13%) | catalogued as rs778901995; called by mutect2, pindel, varscan2
- GALNT5 | c.2239C>T p.R747W | Missense Mutation (SNP) | VAF 193/576 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs765233794, COSV52036829; called by muse, mutect2, varscan2
- GAREM1 | c.1949A>G p.Y650C (on ENST00000269209 / NM_001242409.2; = p.Y649C on NM_022751.3) | Missense Mutation (SNP) | VAF 164/313 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.921); catalogued as COSV99330405; called by muse, mutect2, varscan2
- GAS2 | c.114_116del p.E38del | In Frame Del (DEL) | VAF 119/251 reads (47%) | catalogued as rs1331287600; called by pindel, varscan2
- GAS6 | c.1549G>A p.A517T | Missense Mutation (SNP) | VAF 257/533 reads (48%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs765354911; called by muse, mutect2, varscan2
- GATB | c.826C>T p.R276* | Nonsense Mutation (SNP) | VAF 146/310 reads (47%) | catalogued as rs761557256, COSV56129686, COSV99858960; called by muse, mutect2, varscan2
- GBE1 | c.263G>A p.C88Y | Missense Mutation (SNP) | VAF 148/292 reads (51%) | SIFT tolerated (1); PolyPhen benign (0.02); catalogued as rs1042498; called by muse, mutect2, varscan2
- GDPD4 | c.1632G>T p.K544N | Missense Mutation (SNP) | VAF 201/366 reads (55%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV100264965; called by muse, mutect2, varscan2
- GFOD1 | c.848C>T p.T283M | Missense Mutation (SNP) | VAF 239/699 reads (34%) | SIFT tolerated (0.11); PolyPhen benign (0.045); catalogued as rs763168816, COSV64955232; called by muse, mutect2, varscan2
- GNAS | c.217G>A p.G73S | Missense Mutation (SNP) | VAF 118/261 reads (45%) | SIFT tolerated, low confidence (0.23); PolyPhen possibly damaging (0.595); catalogued as rs587778380; ClinVar: not provided; called by muse, mutect2, varscan2
- GOLGA2 | c.95C>T p.A32V | Missense Mutation (SNP) | VAF 128/297 reads (43%) | SIFT tolerated (0.16); PolyPhen benign (0.027); catalogued as rs994662451; called by muse, mutect2, varscan2
- GOT1L1 | c.1243del p.T415Hfs*2 | Frame Shift Del (DEL) | VAF 154/260 reads (59%) | catalogued as rs370114090; called by mutect2, varscan2
- GP2 | c.1091C>T p.T364M (on ENST00000381362 / NM_001007240.3; = p.T361M on NM_001502.4) | Missense Mutation (SNP) | VAF 95/356 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.975); catalogued as rs759670649; called by muse, mutect2, varscan2
- GPR17 | c.398G>A p.R133H | Missense Mutation (SNP) | VAF 242/765 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs551245718, COSV55754621; called by muse, mutect2, varscan2
- GRIK3 | c.778A>G p.T260A | Missense Mutation (SNP) | VAF 153/307 reads (50%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.611); catalogued as COSV66140701; called by muse, mutect2, varscan2
- GRIK4 | c.971G>A p.R324Q | Missense Mutation (SNP) | VAF 197/390 reads (51%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.953); catalogued as rs779846238, COSV70800239; called by muse, mutect2, varscan2
- GRIN2C | c.1807G>A p.V603M | Missense Mutation (SNP) | VAF 169/352 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); catalogued as rs1378331673, COSV99500900; called by muse, mutect2, varscan2
- GRK7 | c.856C>T p.R286C | Missense Mutation (SNP) | VAF 101/436 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as rs777683287; called by muse, mutect2, varscan2
- GRM1 | c.2497C>T p.P833S | Missense Mutation (SNP) | VAF 235/477 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51151334; called by muse, mutect2, varscan2
- GTF3C1 | c.2299del p.S767Vfs*7 | Frame Shift Del (DEL) | VAF 164/382 reads (43%) | catalogued as rs1231771183; called by mutect2, pindel, varscan2
- GUCA2A | c.329C>T p.A110V | Missense Mutation (SNP) | VAF 57/298 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs139198692; called by muse, mutect2, varscan2
- GZF1 | c.1634G>A p.R545H | Missense Mutation (SNP) | VAF 140/310 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1041287600, COSV57637855; called by muse, varscan2
- HABP2 | c.795G>T p.K265N | Missense Mutation (SNP) | VAF 117/245 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as rs1158919820; called by muse, mutect2, varscan2
- HACE1 | c.1924C>T p.R642W | Missense Mutation (SNP) | VAF 151/323 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as rs771798096, COSV53499112; called by muse, mutect2, varscan2
- HAUS6 | c.1636A>G p.R546G | Missense Mutation (SNP) | VAF 80/171 reads (47%) | SIFT tolerated (0.07); PolyPhen benign (0.116); catalogued as rs1336288456; called by muse, mutect2, varscan2
- HBP1 | c.1130G>A p.R377H | Missense Mutation (SNP) | VAF 146/321 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV99753595; called by muse, mutect2, varscan2
- HDHD3 | c.190G>A p.G64S | Missense Mutation (SNP) | VAF 229/500 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs199715854; called by muse, mutect2, varscan2
- HIF1AN | c.1039C>T p.R347* | Nonsense Mutation (SNP) | VAF 144/324 reads (44%) | catalogued as rs1440667756; called by muse, mutect2, varscan2
- HLCS | c.1744G>A p.G582R | Missense Mutation (SNP) | VAF 107/237 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs376899782, CM021613; called by muse, mutect2, varscan2
- HMX3 | c.413C>T p.A138V | Missense Mutation (SNP) | VAF 153/344 reads (44%) | SIFT tolerated (0.66); PolyPhen benign (0.011); catalogued as COSV63501906; called by muse, mutect2, varscan2
- HOOK1 | c.185G>A p.R62Q | Missense Mutation (SNP) | VAF 114/260 reads (44%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.988); catalogued as rs368144967; called by muse, mutect2, varscan2
- HOXB1 | c.50G>A p.R17Q | Missense Mutation (SNP) | VAF 172/369 reads (47%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs768410617, COSV53317738; called by muse, mutect2, varscan2
- HROB | c.406C>T p.P136S | Missense Mutation (SNP) | VAF 220/450 reads (49%) | SIFT tolerated (0.47); PolyPhen benign (0.04); catalogued as rs762383052; called by muse, mutect2, varscan2
- HSPB3 | c.370G>A p.V124M | Missense Mutation (SNP) | VAF 189/398 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.702); catalogued as rs772793581; called by muse, mutect2, varscan2
- HTT | c.6596C>T p.A2199V | Missense Mutation (SNP) | VAF 147/281 reads (52%) | SIFT tolerated (0.4); PolyPhen benign (0.007); catalogued as rs750741890; called by muse, mutect2, varscan2
- ICA1 | c.611del p.N204Tfs*5 | Frame Shift Del (DEL) | VAF 89/204 reads (44%) | catalogued as rs747841314; called by mutect2, varscan2
- IFFO1 | c.620C>T p.P207L | Missense Mutation (SNP) | VAF 111/641 reads (17%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.707); catalogued as COSV59112779; called by muse, mutect2, varscan2
- IGDCC4 | c.379del p.L127Sfs*55 | Frame Shift Del (DEL) | VAF 222/505 reads (44%) | catalogued as rs1324342372; called by mutect2, pindel, varscan2
- IGHG4 | c.332C>T p.A111V | Missense Mutation (SNP) | VAF 203/413 reads (49%) | SIFT tolerated (0.24); PolyPhen benign (0.061); catalogued as rs753679314; called by muse, mutect2, varscan2
- IGSF9B | c.1260dup p.Y421Lfs*60 | Frame Shift Ins (INS) | VAF 164/332 reads (49%) | catalogued as rs775604395; called by mutect2, varscan2
- IK | c.1001G>A p.R334Q | Missense Mutation (SNP) | VAF 155/337 reads (46%) | SIFT tolerated (0.29); PolyPhen benign (0.043); catalogued as rs367909137, COSV70257699; called by muse, mutect2, varscan2
- IL10 | c.320C>T p.A107V | Missense Mutation (SNP) | VAF 192/378 reads (51%) | SIFT deleterious (0.03); PolyPhen benign (0.02); catalogued as rs755490123, COSV65594355; called by muse, mutect2, varscan2
- IMPDH2 | c.1438C>T p.R480* | Nonsense Mutation (SNP) | VAF 132/240 reads (55%) | catalogued as rs761159150, COSV58247168; called by muse, varscan2
- INHBA | c.876C>A p.F292L | Missense Mutation (SNP) | VAF 238/454 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99637251; called by muse, varscan2
- INPPL1 | c.1456C>T p.R486C | Missense Mutation (SNP) | VAF 182/393 reads (46%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); catalogued as rs1006478277, COSV53357512; called by muse, mutect2, varscan2
- INPPL1 | c.3466del p.R1156Gfs*46 | Frame Shift Del (DEL) | VAF 292/731 reads (40%) | catalogued as rs760925109; called by mutect2, pindel, varscan2
- IQCK | c.329G>A p.R110H | Missense Mutation (SNP) | VAF 146/299 reads (49%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as rs560311228, COSV57521975; called by muse, mutect2, varscan2
- IQGAP1 | c.4477C>T p.R1493W | Missense Mutation (SNP) | VAF 94/251 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as rs768558979; called by muse, mutect2, varscan2
- IQSEC1 | c.436C>T p.R146C | Missense Mutation (SNP) | VAF 209/444 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56229085; called by muse, mutect2, varscan2
- ITFG2 | c.955G>A p.G319R | Missense Mutation (SNP) | VAF 170/311 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs751656032, COSV57389046; called by muse, mutect2, varscan2
- ITGB8 | c.1865G>A p.R622H | Missense Mutation (SNP) | VAF 133/269 reads (49%) | SIFT tolerated (0.16); PolyPhen benign (0.006); catalogued as rs767838901; called by muse, mutect2, varscan2
- ITPRIPL2 | c.1250G>A p.R417H | Missense Mutation (SNP) | VAF 195/462 reads (42%) | SIFT tolerated (0.22); PolyPhen benign (0.006); catalogued as rs759664422; called by muse, mutect2, varscan2
- JAKMIP2 | c.395C>T p.A132V | Missense Mutation (SNP) | VAF 190/411 reads (46%) | SIFT tolerated (0.53); PolyPhen benign (0.001); catalogued as rs1228466489, COSV54618000; called by muse, mutect2, varscan2
- JPH2 | c.937C>T p.R313C | Missense Mutation (SNP) | VAF 285/632 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.878); catalogued as COSV65904077; called by muse, mutect2, varscan2
- JPH3 | c.1309C>T p.R437C | Missense Mutation (SNP) | VAF 177/355 reads (50%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as rs759077257, COSV104370505; called by muse, mutect2, varscan2
- KANK2 | c.1967T>C p.L656P (on ENST00000586659 / NM_001379562.1; = p.L664P on NM_015493.7 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 229/473 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1327454879; called by muse, mutect2, varscan2
- KANSL3 | c.226G>A p.V76I | Missense Mutation (SNP) | VAF 130/404 reads (32%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs760552557; called by muse, mutect2, varscan2
- KAT14 | c.488dup p.L163Ffs*5 | Frame Shift Ins (INS) | VAF 76/232 reads (33%) | catalogued as rs1480801806; called by mutect2, pindel, varscan2
- KATNB1 | c.526C>T p.L176F | Missense Mutation (SNP) | VAF 142/289 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV65559604; called by muse, mutect2, varscan2
- KATNIP | c.2665C>T p.R889C | Missense Mutation (SNP) | VAF 204/424 reads (48%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs767622231; called by muse, mutect2, varscan2
- KBTBD6 | c.760C>T p.R254W | Missense Mutation (SNP) | VAF 221/442 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs61999308; called by muse, mutect2, varscan2
- KCNA4 | c.663del p.F221Lfs*21 | Frame Shift Del (DEL) | VAF 160/366 reads (44%) | catalogued as rs754892524; called by mutect2, varscan2
- KCNA4 | c.23C>T p.A8V | Missense Mutation (SNP) | VAF 129/256 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as rs1221863870, COSV100068956; called by muse, varscan2
- KCNC4 | c.1024G>A p.V342M | Missense Mutation (SNP) | VAF 256/519 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.358); catalogued as rs765248480, COSV63924979; called by muse, varscan2
- KCNMA1 | c.1408G>A p.V470I | Missense Mutation (SNP) | VAF 150/291 reads (52%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.658); catalogued as rs149000684, COSV54266518; called by muse, mutect2, varscan2
- KCNMA1 | c.1306G>A p.V436I | Missense Mutation (SNP) | VAF 133/292 reads (46%) | SIFT tolerated (0.48); PolyPhen probably damaging (0.956); catalogued as rs762346849, COSV54259883; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KIF1B | c.3140C>T p.S1047L (on ENST00000377086 / NM_001365952.1; = p.S1001L on NM_015074.3) | Missense Mutation (SNP) | VAF 95/209 reads (45%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs267597898, COSV55811951; called by muse, mutect2, varscan2
- KIF20A | c.241C>T p.R81* | Nonsense Mutation (SNP) | VAF 141/285 reads (49%) | catalogued as rs779440603; called by muse, mutect2, varscan2
- KIF2A | c.562G>A p.V188I | Missense Mutation (SNP) | VAF 70/155 reads (45%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs777382535, COSV66945840; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KIF5B | c.1216G>A p.A406T | Missense Mutation (SNP) | VAF 158/335 reads (47%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as rs377656602; called by muse, mutect2, varscan2
- KLHL17 | c.767A>G p.Y256C | Missense Mutation (SNP) | VAF 40/371 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs371445171; called by muse, mutect2
- KLRG2 | c.1151G>A p.G384E | Missense Mutation (SNP) | VAF 208/404 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.587); catalogued as rs1218084165, COSV61800901; called by muse, mutect2, varscan2
- KMT2B | c.7154A>G p.Y2385C | Missense Mutation (SNP) | VAF 50/281 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV55866560; called by muse, mutect2, varscan2
- L3MBTL1 | c.2236C>T p.R746C (on ENST00000418998 / NM_001377303.1; = p.R656C on NM_015478.7) | Missense Mutation (SNP) | VAF 195/400 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs144951279; called by muse, mutect2, varscan2
- LAMA2 | c.442del p.R148Gfs*24 | Frame Shift Del (DEL) | VAF 144/344 reads (42%) | catalogued as COSV70345971; called by mutect2, pindel, varscan2
- LAMB4 | c.3443G>A p.R1148H | Missense Mutation (SNP) | VAF 93/397 reads (23%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs772132232; called by muse, mutect2, varscan2
- LAP3 | c.521C>T p.S174L | Missense Mutation (SNP) | VAF 97/211 reads (46%) | SIFT tolerated (0.21); PolyPhen benign (0.011); catalogued as rs374750225; called by muse, mutect2, varscan2
- LGALS13 | c.323G>A p.R108H | Missense Mutation (SNP) | VAF 140/260 reads (54%) | SIFT tolerated (0.6); PolyPhen benign (0.003); catalogued as rs1303608067, COSV99695050; called by muse, mutect2, varscan2
- LGI2 | c.832G>A p.V278M | Missense Mutation (SNP) | VAF 162/346 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs767382221, COSV66123864; called by muse, mutect2, varscan2
- LHX9 | c.1034C>T p.P345L | Missense Mutation (SNP) | VAF 217/443 reads (49%) | SIFT tolerated (0.76); PolyPhen benign (0.001); catalogued as rs1308471113; called by muse, mutect2, varscan2
- LIPM | c.592A>G p.T198A | Missense Mutation (SNP) | VAF 126/271 reads (46%) | SIFT tolerated (0.05); PolyPhen benign (0.035); catalogued as rs755215464; called by muse, mutect2, varscan2
- LLGL1 | c.1660G>A p.V554M | Missense Mutation (SNP) | VAF 202/394 reads (51%) | SIFT tolerated (0.13); PolyPhen benign (0.048); catalogued as rs759554948; called by muse, mutect2, varscan2
- LMF2 | c.578C>T p.A193V | Missense Mutation (SNP) | VAF 197/400 reads (49%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.461); catalogued as rs558923692; called by muse, varscan2
- LMX1A | c.41C>T p.A14V | Missense Mutation (SNP) | VAF 208/402 reads (52%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.003); catalogued as rs749385148, COSV99673081; called by muse, mutect2, varscan2
- LONP1 | c.1702G>A p.A568T | Missense Mutation (SNP) | VAF 157/304 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99052281; called by muse, mutect2, varscan2
- LPCAT4 | c.1051C>T p.R351W | Missense Mutation (SNP) | VAF 161/347 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.226); catalogued as rs776501231; called by muse, mutect2, varscan2
- LRBA | c.499C>T p.R167C | Missense Mutation (SNP) | VAF 110/228 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs371936024; called by muse, mutect2, varscan2
- LRIG1 | c.890G>A p.R297H | Missense Mutation (SNP) | VAF 153/350 reads (44%) | SIFT tolerated (0.12); PolyPhen benign (0.037); catalogued as rs373112316; called by muse, mutect2, varscan2
- LRP1 | c.6964C>T p.R2322C | Missense Mutation (SNP) | VAF 196/400 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1403053376; called by muse, varscan2
- LRP2 | c.6565G>A p.V2189M | Missense Mutation (SNP) | VAF 85/578 reads (15%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.819); catalogued as COSV99788295; called by muse, mutect2, varscan2
- LRRC37A2 | c.3613dup p.R1205Kfs*20 | Frame Shift Ins (INS) | VAF 256/842 reads (30%) | catalogued as rs1567980464; called by mutect2, varscan2
- LRRC4B | c.497G>A p.R166Q | Missense Mutation (SNP) | VAF 260/498 reads (52%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.856); catalogued as COSV65349201; called by muse, mutect2, varscan2
- LRRFIP1 | c.175C>T p.R59C | Missense Mutation (SNP) | VAF 318/478 reads (67%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as rs375809493; called by muse, mutect2, varscan2
- LY6G6F-LY6G6D | c.506G>A p.R169H | Missense Mutation (SNP) | VAF 336/1136 reads (30%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as rs908403443, COSV65442557; called by muse, mutect2
- MAGEB16 | c.695C>T p.T232M | Missense Mutation (SNP) | VAF 319/320 reads (100%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as rs774566572, COSV104433685; called by muse, mutect2, varscan2
- MAGEC3 | c.509C>T p.A170V | Missense Mutation (SNP) | VAF 158/158 reads (100%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs369863174, COSV71610185; called by muse, mutect2
- MAP9 | c.1700del p.K567Rfs*13 | Frame Shift Del (DEL) | VAF 52/139 reads (37%) | catalogued as rs1215313075; called by mutect2, pindel, varscan2
- MBD6 | c.2080del p.Q694Sfs*5 | Frame Shift Del (DEL) | VAF 76/178 reads (43%) | catalogued as rs762648935; called by mutect2, pindel, varscan2
- MBTD1 | c.715G>A p.G239R | Missense Mutation (SNP) | VAF 171/347 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.566); catalogued as rs747834993; called by muse, mutect2, varscan2
- MCC | c.652C>T p.R218W | Missense Mutation (SNP) | VAF 165/320 reads (52%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.898); catalogued as rs537132002; called by muse, mutect2, varscan2
- MCCC2 | c.578G>A p.R193H | Missense Mutation (SNP) | VAF 51/328 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.95); catalogued as rs535519604, CM062848; called by muse, mutect2, varscan2
- MCL1 | c.424C>T p.P142S | Missense Mutation (SNP) | VAF 239/464 reads (52%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.702); catalogued as rs767724723; called by muse, mutect2, varscan2
- MCM2 | c.455G>A p.R152H | Missense Mutation (SNP) | VAF 203/397 reads (51%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.985); catalogued as rs200231306, COSV54031921; called by muse, varscan2
- MDN1 | c.5966del p.K1989Rfs*65 | Frame Shift Del (DEL) | VAF 102/208 reads (49%) | catalogued as rs750092100; called by mutect2, varscan2
- MDN1 | c.2278C>T p.R760W | Missense Mutation (SNP) | VAF 169/349 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs773314424; called by muse, mutect2, varscan2
- MED12L | c.1004G>C p.G335A | Missense Mutation (SNP) | VAF 178/420 reads (42%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56374716, COSV56376808; called by mutect2, varscan2
- MEGF6 | c.4318dup p.A1440Gfs*4 | Frame Shift Ins (INS) | VAF 226/490 reads (46%) | catalogued as rs759225724; called by mutect2, varscan2
- MET | c.1483A>G p.T495A | Missense Mutation (SNP) | VAF 180/332 reads (54%) | SIFT tolerated (0.65); PolyPhen benign (0.048); catalogued as COSV59259596; called by muse, mutect2, varscan2
- MGAM | c.2167C>A p.L723I | Missense Mutation (SNP) | VAF 154/350 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); catalogued as COSV72075778; called by muse, mutect2, varscan2
- MGAM2 | c.3242G>A p.R1081H | Missense Mutation (SNP) | VAF 90/305 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs962020717, COSV101522899; called by muse, mutect2, varscan2
- MOB2 | c.269A>G p.Y90C | Missense Mutation (SNP) | VAF 173/339 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs777745822; called by muse, mutect2, varscan2
- MPL | c.1277G>A p.R426Q | Missense Mutation (SNP) | VAF 131/292 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs200454070, COSV99055374; called by muse, mutect2, varscan2
- MPST | c.808C>G p.P270A (on ENST00000341116 / NM_001369904.2; = p.P290A on NM_021126.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 296/576 reads (51%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1174078099; called by muse, mutect2, varscan2
- MRC2 | c.617G>A p.R206H | Missense Mutation (SNP) | VAF 206/444 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs765734147; called by muse, mutect2, varscan2
- MSH4 | c.2728C>T p.R910* | Nonsense Mutation (SNP) | VAF 135/270 reads (50%) | catalogued as rs771456188, COSV99592878; called by muse, mutect2, varscan2
- MTCH2 | c.860G>A p.R287Q | Missense Mutation (SNP) | VAF 132/246 reads (54%) | SIFT deleterious (0.04); PolyPhen benign (0.337); catalogued as rs77581661, COSV56766844; called by muse, mutect2, varscan2
- MTLN | c.193C>T p.R65C | Missense Mutation (SNP) | VAF 57/409 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.685); catalogued as rs1317641259; called by muse, mutect2, varscan2
- MTMR4 | c.932C>T p.A311V | Missense Mutation (SNP) | VAF 41/334 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60199364; called by muse, mutect2, varscan2
- MUC12 | c.1823C>T p.S608L (on ENST00000379442; = p.S465L on NM_001164462.1) | Missense Mutation (SNP) | VAF 197/673 reads (29%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.316); catalogued as rs12533349, COSV65199517; called by muse, mutect2, varscan2
- MUC16 | c.40646C>T p.A13549V | Missense Mutation (SNP) | VAF 111/231 reads (48%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.847); catalogued as COSV101109820; called by muse, mutect2, varscan2
- MUC5B | c.5000G>A p.G1667D | Missense Mutation (SNP) | VAF 122/654 reads (19%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as COSV71596496; called by muse, mutect2, varscan2
- MXRA8 | c.901del p.R301Gfs*107 | Frame Shift Del (DEL) | VAF 211/539 reads (39%) | catalogued as rs764857791; called by mutect2, pindel, varscan2
- MYBPC1 | c.2882C>T p.A961V (on ENST00000550270 / NM_206820.2; = p.A968V on NM_002465.4) | Missense Mutation (SNP) | VAF 175/342 reads (51%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.474); catalogued as rs755894383; called by muse, mutect2, varscan2
- MYBPC3 | c.1288G>A p.D430N | Missense Mutation (SNP) | VAF 82/388 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs730880534; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYH7 | c.3508G>A p.E1170K | Missense Mutation (SNP) | VAF 120/366 reads (33%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); catalogued as rs750627218; called by muse, mutect2, varscan2
- MYMK | c.130G>A p.V44M | Missense Mutation (SNP) | VAF 152/298 reads (51%) | SIFT tolerated (0.07); PolyPhen benign (0.127); catalogued as rs770599578; called by muse, mutect2, varscan2
- MYO15A | c.10250C>T p.S3417F | Missense Mutation (SNP) | VAF 181/367 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as CD153987, COSV52767696; called by muse, mutect2, varscan2
- MYO1A | c.2141G>A p.R714H | Missense Mutation (SNP) | VAF 177/368 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs369452147; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- MYORG | c.827C>T p.A276V | Missense Mutation (SNP) | VAF 231/474 reads (49%) | SIFT tolerated (0.49); PolyPhen benign (0.015); catalogued as rs1469373049; called by muse, mutect2, varscan2
- NAA60 | c.131G>A p.R44H | Missense Mutation (SNP) | VAF 133/263 reads (51%) | SIFT deleterious (0.05); PolyPhen benign (0.007); catalogued as rs1374516163; called by muse, mutect2, varscan2
- NBEAL2 | c.6007C>T p.P2003S | Missense Mutation (SNP) | VAF 255/533 reads (48%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as COSV52754366; called by muse, mutect2, varscan2
- NCKIPSD | c.1612G>A p.V538I | Missense Mutation (SNP) | VAF 139/294 reads (47%) | SIFT tolerated (1); PolyPhen benign (0.041); catalogued as rs371383008; called by muse, mutect2, varscan2
- NCKIPSD | c.239G>A p.R80Q | Missense Mutation (SNP) | VAF 160/363 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.041); catalogued as rs376825176; called by muse, mutect2, varscan2
- NCOA2 | c.3956C>T p.T1319M | Missense Mutation (SNP) | VAF 148/312 reads (47%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.482); catalogued as rs774257324, COSV51219736; called by muse, mutect2, varscan2
- NCOR2 | c.3178dup p.R1060Pfs*2 | Frame Shift Ins (INS) | VAF 236/482 reads (49%) | catalogued as rs749518211; called by mutect2, varscan2
- NDRG1 | c.1057C>T p.R353C | Missense Mutation (SNP) | VAF 300/621 reads (48%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.98); catalogued as rs777244818; called by muse, mutect2, varscan2
- NDRG4 | c.310G>A p.G104R (on ENST00000570248 / NM_001378344.1; = p.G136R on NM_020465.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 229/455 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs369106170, COSV50746448, COSV99059954; called by muse, mutect2, varscan2
- NDUFA9 | c.601G>A p.V201I | Missense Mutation (SNP) | VAF 193/333 reads (58%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs201865179; called by muse, mutect2, varscan2
- NECTIN1 | c.1145G>A p.R382Q | Missense Mutation (SNP) | VAF 227/474 reads (48%) | SIFT tolerated (0.4); PolyPhen benign (0.011); catalogued as rs371158952, COSV50598077; called by muse, mutect2, varscan2
- NELFE | c.142C>T p.R48C | Missense Mutation (SNP) | VAF 201/676 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.848); catalogued as rs754439377, COSV100952920; called by muse, mutect2, varscan2
- NEURL1 | c.898C>T p.R300C | Missense Mutation (SNP) | VAF 141/231 reads (61%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.926); catalogued as rs1309128120, COSV63914132; called by muse, mutect2, varscan2
- NFATC1 | c.883G>A p.V295M | Missense Mutation (SNP) | VAF 275/564 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.923); catalogued as rs139882199; called by muse, mutect2, varscan2
- NFATC2 | c.2687A>G p.Q896R | Missense Mutation (SNP) | VAF 148/303 reads (49%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.979); catalogued as COSV65357837; called by muse, mutect2, varscan2
- NFATC2IP | c.787del p.R263Dfs*60 | Frame Shift Del (DEL) | VAF 241/541 reads (45%) | catalogued as rs765645344; called by mutect2, pindel, varscan2
- NLRP6 | c.112C>T p.R38C | Missense Mutation (SNP) | VAF 234/464 reads (50%) | SIFT tolerated (0.07); PolyPhen benign (0.013); catalogued as rs1379500532; called by muse, varscan2
- NOL12 | c.347C>T p.S116L | Missense Mutation (SNP) | VAF 167/392 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.081); catalogued as rs141277853; called by muse, mutect2, varscan2
- NOTCH1 | c.5189C>T p.P1730L | Missense Mutation (SNP) | VAF 175/390 reads (45%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as rs375897519; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- NPAP1 | c.511G>T p.G171W | Missense Mutation (SNP) | VAF 186/397 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV61507839; called by muse, mutect2, varscan2
- NPHS1 | c.2597G>A p.R866Q | Missense Mutation (SNP) | VAF 211/395 reads (53%) | SIFT tolerated (0.37); PolyPhen benign (0.218); catalogued as rs868576714; called by muse, mutect2, varscan2
- NPR1 | c.1818dup p.N607Qfs*21 | Frame Shift Ins (INS) | VAF 126/242 reads (52%) | catalogued as rs772189906; called by mutect2, varscan2
- NR2C2 | c.322G>A p.V108I (on ENST00000393102; = p.V127I on NM_003298.5) | Missense Mutation (SNP) | VAF 180/335 reads (54%) | SIFT tolerated (0.47); PolyPhen benign (0.014); catalogued as rs762221262, COSV60146632; called by muse, mutect2, varscan2
- NRG1 | c.245del p.P82Lfs*26 (on ENST00000523534; = p.P229Lfs*26 on NM_013962.2) | Frame Shift Del (DEL) | VAF 154/421 reads (37%) | catalogued as COSV73059882; called by mutect2, pindel, varscan2
- NRXN2 | c.1996C>T p.R666C | Missense Mutation (SNP) | VAF 220/520 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs769291803, COSV55447013; called by muse, mutect2, varscan2
- NSD3 | c.959C>T p.A320V | Missense Mutation (SNP) | VAF 132/269 reads (49%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as rs1250796714, COSV57619196; called by muse, mutect2, varscan2
- NSMAF | c.2131A>G p.M711V | Missense Mutation (SNP) | VAF 110/266 reads (41%) | SIFT tolerated (0.09); PolyPhen benign (0.07); catalogued as rs529100436; called by muse, mutect2, varscan2
- NTRK1 | c.1298C>A p.S433Y | Missense Mutation (SNP) | VAF 179/372 reads (48%) | SIFT tolerated (1); PolyPhen benign (0.269); catalogued as COSV62328403; called by muse, mutect2, varscan2
- NUDT18 | c.934C>T p.R312W | Missense Mutation (SNP) | VAF 136/262 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs776397436, COSV57158831; called by muse, mutect2, varscan2
- NUP210L | c.3367G>A p.V1123M | Missense Mutation (SNP) | VAF 209/416 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs746145392, COSV99666932; called by muse, mutect2, varscan2
- OBSL1 | c.1024C>T p.R342W | Missense Mutation (SNP) | VAF 166/365 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs767009179, COSV54718742; called by muse, mutect2, varscan2
- ODF3L1 | c.328C>T p.R110C | Missense Mutation (SNP) | VAF 95/213 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.886); catalogued as rs757435984; called by muse, mutect2, varscan2
- OLFML1 | c.281G>A p.R94H | Missense Mutation (SNP) | VAF 184/348 reads (53%) | SIFT deleterious (0.05); PolyPhen benign (0.369); catalogued as rs774002516, COSV61401793; called by muse, mutect2, varscan2
- OLFML2B | c.1783G>A p.V595M | Missense Mutation (SNP) | VAF 233/452 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs780805933, COSV54200720; called by muse, mutect2, varscan2
- OPA1 | c.2818C>T p.R940C (on ENST00000361510 / NM_130837.3; = p.R885C on NM_015560.3) | Missense Mutation (SNP) | VAF 128/272 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs927450242; called by muse, varscan2
- OR10J3 | c.818G>A p.R273K | Missense Mutation (SNP) | VAF 181/414 reads (44%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.542); catalogued as rs1395137790; called by muse, mutect2, varscan2
- OR12D2 | c.460G>A p.A154T | Missense Mutation (SNP) | VAF 625/944 reads (66%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.985); catalogued as rs765400893; called by muse, mutect2, varscan2
- OR1C1 | c.757G>A p.G253S | Missense Mutation (SNP) | VAF 192/391 reads (49%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs376185600; called by muse, mutect2, varscan2
- OR4C11 | c.884C>T p.A295V | Missense Mutation (SNP) | VAF 183/350 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.619); catalogued as rs1446936576; called by muse, mutect2, varscan2
- OR4D5 | c.455del p.G152Afs*6 | Frame Shift Del (DEL) | VAF 202/515 reads (39%) | catalogued as COSV58306683; called by mutect2, pindel, varscan2
- OR4P4 | c.22A>G p.T8A | Missense Mutation (SNP) | VAF 123/248 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs770410713; called by muse, mutect2, varscan2
- OR52E4 | c.400T>C p.Y134H | Missense Mutation (SNP) | VAF 160/464 reads (34%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.452); catalogued as rs1399103467, COSV100389211; called by muse, mutect2, varscan2
- ORC5 | c.1144del p.S382Pfs*6 | Frame Shift Del (DEL) | VAF 94/221 reads (43%) | catalogued as COSV99856914; called by mutect2, pindel, varscan2
- OSBPL2 | c.543dup p.I182Hfs*12 (on ENST00000313733 / NM_144498.4; = p.I170Hfs*12 on NM_014835.4) | Frame Shift Ins (INS) | VAF 202/400 reads (51%) | catalogued as rs780916980; called by mutect2, varscan2
- OSBPL2 | c.1113del p.N372Tfs*13 (on ENST00000313733 / NM_144498.4; = p.N360Tfs*13 on NM_014835.4) | Frame Shift Del (DEL) | VAF 124/260 reads (48%) | catalogued as COSV58215176; called by mutect2, varscan2
- P4HA1 | c.592G>A p.E198K | Missense Mutation (SNP) | VAF 198/390 reads (51%) | SIFT tolerated (0.09); PolyPhen benign (0.091); catalogued as rs1024039064; called by muse, mutect2, varscan2
- PALM2AKAP2 | c.1114C>T p.R372C (on ENST00000374531 / NM_001037293.2; = p.R404C on NM_053016.6) | Missense Mutation (SNP) | VAF 141/312 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs535977013, COSV57117854; called by muse, mutect2, varscan2
- PAX7 | c.896C>T p.T299M | Missense Mutation (SNP) | VAF 343/657 reads (52%) | SIFT deleterious (0.03); PolyPhen benign (0.444); catalogued as COSV100946958; called by muse, mutect2
- PCDHB1 | c.205G>A p.E69K | Missense Mutation (SNP) | VAF 190/420 reads (45%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as rs1554267053; called by muse, mutect2, varscan2
- PCDHB3 | c.1736C>T p.A579V | Missense Mutation (SNP) | VAF 383/764 reads (50%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.244); catalogued as rs782146000, COSV50608941; called by muse, mutect2, varscan2
- PCDHGB1 | c.1414G>A p.A472T | Missense Mutation (SNP) | VAF 282/527 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs781547082, COSV53976716; called by muse, mutect2, varscan2
- PCDHGB6 | c.1645C>T p.R549C | Missense Mutation (SNP) | VAF 202/429 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.478); catalogued as COSV53946573; called by muse, mutect2, varscan2
- PCP4 | c.133G>A p.A45T | Missense Mutation (SNP) | VAF 130/302 reads (43%) | SIFT tolerated (0.15); PolyPhen benign (0.071); catalogued as COSV60787097; called by muse, mutect2, varscan2
- PDE1B | c.292C>T p.R98W | Missense Mutation (SNP) | VAF 203/406 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1324446563, COSV54496889; called by muse, mutect2, varscan2
- PDE1B | c.1148G>A p.R383H | Missense Mutation (SNP) | VAF 137/272 reads (50%) | SIFT tolerated (0.05); PolyPhen benign (0.381); catalogued as rs1016670941; called by muse, mutect2, varscan2
- PFDN6 | c.295C>T p.R99W | Missense Mutation (SNP) | VAF 70/504 reads (14%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.97); catalogued as rs771077401; called by muse, varscan2
- PGAM2 | c.322G>A p.G108R | Missense Mutation (SNP) | VAF 258/502 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs374395743; called by muse, mutect2, varscan2
- PHC2 | c.1210G>A p.A404T | Missense Mutation (SNP) | VAF 268/540 reads (50%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs747950368; called by muse, mutect2, varscan2
- PHC2 | c.998A>G p.H333R | Missense Mutation (SNP) | VAF 38/342 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs1409182201; called by muse, mutect2, varscan2
- PHRF1 | c.580C>T p.R194C | Missense Mutation (SNP) | VAF 196/447 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1398196971, COSV99213401; called by muse, mutect2, varscan2
- PI16 | c.215G>A p.R72Q | Missense Mutation (SNP) | VAF 251/768 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV65448100; called by muse, mutect2, varscan2
- PIGQ | c.64C>T p.R22W | Missense Mutation (SNP) | VAF 249/494 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.981); catalogued as rs751055581; called by muse, mutect2, varscan2
- PIK3C2A | c.4339C>T p.R1447* | Nonsense Mutation (SNP) | VAF 89/175 reads (51%) | catalogued as rs747073851, COSV56405609; called by muse, mutect2, varscan2
- PINK1 | c.853G>A p.V285M | Missense Mutation (SNP) | VAF 60/570 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.859); catalogued as rs557503577, COSV58630730, COSV58632345; called by muse, mutect2
- PIWIL2 | c.1504G>A p.G502R | Missense Mutation (SNP) | VAF 86/273 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs138817329; called by muse, mutect2, varscan2
- PKD1 | c.12779G>A p.R4260H (on ENST00000262304 / NM_001009944.3; = p.R4259H on NM_000296.4) | Missense Mutation (SNP) | VAF 281/574 reads (49%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs750700500; called by muse, mutect2, varscan2
- PKD2 | c.2461G>A p.G821R | Missense Mutation (SNP) | VAF 37/391 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV52938517; called by muse, mutect2
- PKP2 | c.688G>A p.V230I | Missense Mutation (SNP) | VAF 225/459 reads (49%) | SIFT tolerated (0.09); PolyPhen benign (0.015); catalogued as rs543281875, COSV50726677; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PLAC8L1 | c.179C>T p.T60M | Missense Mutation (SNP) | VAF 163/338 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.591); catalogued as rs776737291, COSV61013573; called by muse, mutect2, varscan2
- PLCE1 | c.1312G>A p.V438I | Missense Mutation (SNP) | VAF 180/396 reads (45%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0.006); catalogued as rs1482772158, COSV53357049; called by muse, mutect2, varscan2
- PLD1 | c.2081C>T p.A694V | Missense Mutation (SNP) | VAF 153/322 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV100577663, COSV60565858; called by muse, mutect2, varscan2
- PLEC | c.12337G>A p.V4113I (on ENST00000322810 / NM_201380.4; = p.V4003I on NM_000445.5) | Missense Mutation (SNP) | VAF 202/435 reads (46%) | SIFT tolerated (0.44); PolyPhen benign (0.12); catalogued as rs782422260; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PLEC | c.5471G>A p.R1824Q (on ENST00000322810 / NM_201380.4; = p.R1714Q on NM_000445.5) | Missense Mutation (SNP) | VAF 321/667 reads (48%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.062); catalogued as rs563046387; called by muse, mutect2, varscan2
- PLEKHB2 | c.538T>C p.Y180H (on ENST00000409279; = p.Y179H on NM_017958.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 118/350 reads (34%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.996); catalogued as COSV52178392; called by muse, mutect2, varscan2
- PLOD2 | c.2041G>A p.V681M | Missense Mutation (SNP) | VAF 38/152 reads (25%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.803); catalogued as rs780062874, COSV51462682; called by muse, mutect2, varscan2
- PLXNB1 | c.536del p.G179Vfs*41 | Frame Shift Del (DEL) | VAF 205/476 reads (43%) | catalogued as rs953293505; called by mutect2, varscan2
- PLXNB2 | c.3993+1G>A p.X1331_splice | Splice Site (SNP) | VAF 122/237 reads (51%) | catalogued as COSV100834014; called by muse, mutect2, varscan2
- PLXNB2 | c.556C>T p.R186W | Missense Mutation (SNP) | VAF 278/576 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); catalogued as rs531070913, COSV63783054; called by muse, mutect2, varscan2
- PNPLA2 | c.649C>T p.R217C | Missense Mutation (SNP) | VAF 196/385 reads (51%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.786); catalogued as rs773938209; called by muse, mutect2, varscan2
- PNPLA8 | c.133A>G p.S45G | Missense Mutation (SNP) | VAF 148/324 reads (46%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0.026); catalogued as rs1261274636; called by muse, mutect2, varscan2
- POGZ | c.3014G>A p.R1005H | Missense Mutation (SNP) | VAF 204/410 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.976); catalogued as rs748955181; called by muse, varscan2
- POLR3E | c.1747C>T p.R583C | Missense Mutation (SNP) | VAF 179/388 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as rs1463897933; called by muse, varscan2
- POMC | c.256C>T p.R86* | Nonsense Mutation (SNP) | VAF 133/803 reads (17%) | catalogued as rs1181875747, CM123452; called by muse, mutect2, varscan2
- POTEC | c.810G>T p.K270N | Missense Mutation (SNP) | VAF 76/193 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100743265, COSV100743946; called by muse, mutect2, varscan2
- PPM1D | c.1349dup p.L450Ffs*6 | Frame Shift Ins (INS) | VAF 174/450 reads (39%) | catalogued as rs758630849; called by mutect2, pindel, varscan2
- PPP1R26 | c.2692del p.V898Sfs*56 | Frame Shift Del (DEL) | VAF 248/574 reads (43%) | catalogued as rs1365223299; called by pindel, varscan2
- PPP1R3F | c.1789G>A p.E597K | Missense Mutation (SNP) | VAF 18/392 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.824); catalogued as COSV50020613; called by muse, mutect2
- PPP3R2 | c.148C>T p.R50C | Missense Mutation (SNP) | VAF 239/464 reads (52%) | SIFT deleterious (0.03); PolyPhen benign (0.013); catalogued as rs746497872, COSV62452747; called by muse, mutect2, varscan2
- PRDM16 | c.2057C>T p.T686M | Missense Mutation (SNP) | VAF 240/492 reads (49%) | SIFT deleterious (0.02); PolyPhen benign (0.151); catalogued as rs868332674; ClinVar: uncertain significance; called by muse, varscan2
- PRDM16 | c.2635G>A p.V879M | Missense Mutation (SNP) | VAF 175/345 reads (51%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.828); catalogued as rs746861136; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PRKCD | c.224G>T p.R75L | Missense Mutation (SNP) | VAF 180/404 reads (45%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as COSV57851416; called by muse, varscan2
- PRKD3 | c.2020C>T p.R674* | Nonsense Mutation (SNP) | VAF 203/329 reads (62%) | catalogued as rs1404288610; called by muse, mutect2, varscan2
- PRLHR | c.374G>A p.R125H | Missense Mutation (SNP) | VAF 141/570 reads (25%) | SIFT tolerated (0.19); PolyPhen benign (0.041); catalogued as rs1328613305, COSV53302763; called by muse, mutect2, varscan2
- PRPF4 | c.586C>T p.R196* (on ENST00000374198 / NM_001322267.2; = p.R197* on NM_004697.5) | Nonsense Mutation (SNP) | VAF 113/260 reads (43%) | catalogued as COSV65253166; called by muse, mutect2, varscan2
- PRPSAP1 | c.376C>A p.P126T | Missense Mutation (SNP) | VAF 198/400 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV61211222; called by muse, mutect2, varscan2
- PRR23A | c.514G>A p.A172T | Missense Mutation (SNP) | VAF 232/454 reads (51%) | SIFT tolerated (0.22); PolyPhen benign (0.007); catalogued as rs1241419687, COSV67215212; called by muse, varscan2
- PRRC2A | c.1276C>G p.P426A | Missense Mutation (SNP) | VAF 224/728 reads (31%) | SIFT tolerated (0.57); PolyPhen probably damaging (0.991); catalogued as rs1029003133; called by muse, mutect2
- PRRC2C | c.1711C>T p.R571W (on ENST00000367742; = p.R569W on NM_015172.4) | Missense Mutation (SNP) | VAF 169/375 reads (45%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.001); catalogued as rs373214431; called by muse, mutect2, varscan2
- PRSS36 | c.2038del p.L680Wfs*6 | Frame Shift Del (DEL) | VAF 288/644 reads (45%) | catalogued as rs771809480; called by mutect2, pindel, varscan2
- PRX | c.3091C>T p.R1031W | Missense Mutation (SNP) | VAF 223/514 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1399950077, COSV99397952; called by muse, mutect2, varscan2
- PTPRK | c.4192C>T p.R1398W (on ENST00000368215 / NM_001291984.2; = p.R1399W on NM_002844.4) | Missense Mutation (SNP) | VAF 160/316 reads (51%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.959); catalogued as rs370374055; called by muse, mutect2, varscan2
- PTPRN | c.92del p.G31Afs*75 | Frame Shift Del (DEL) | VAF 121/280 reads (43%) | catalogued as rs1179811215; called by mutect2, pindel, varscan2
- PWWP2A | c.2239C>T p.R747W | Missense Mutation (SNP) | VAF 128/247 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as rs1199611967; called by muse, mutect2, varscan2
- PYGM | c.1316G>A p.R439H | Missense Mutation (SNP) | VAF 246/492 reads (50%) | SIFT tolerated (0.06); PolyPhen benign (0.104); catalogued as rs769479715, COSV99376579; called by muse, varscan2
- QSOX1 | c.2075G>A p.R692Q | Missense Mutation (SNP) | VAF 247/500 reads (49%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as rs758947386, COSV100852971; called by muse, mutect2, varscan2
- RAD51AP1 | c.208del p.R70Dfs*21 (on ENST00000228843 / NM_001130862.2; = p.R70Gfs*4 on NM_006479.5) | Frame Shift Del (DEL) | VAF 241/389 reads (62%) | catalogued as rs745353960; called by mutect2, pindel, varscan2
- RASGEF1A | c.610G>A p.A204T | Missense Mutation (SNP) | VAF 242/497 reads (49%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs767084570, COSV65666676; called by muse, mutect2, varscan2
- RASGRP1 | c.2222G>A p.R741H | Missense Mutation (SNP) | VAF 89/168 reads (53%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0); catalogued as rs201585269, COSV60367713; called by muse, mutect2, varscan2
- RASIP1 | c.1216G>A p.V406M | Missense Mutation (SNP) | VAF 151/286 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.669); catalogued as rs1372516730; called by muse, varscan2
- RBFA | c.895G>A p.E299K | Missense Mutation (SNP) | VAF 227/438 reads (52%) | SIFT tolerated (0.43); PolyPhen benign (0.005); catalogued as rs372074483; called by muse, mutect2, varscan2
- RBM33 | c.857G>A p.R286H | Missense Mutation (SNP) | VAF 162/363 reads (45%) | SIFT tolerated (0.76); PolyPhen benign (0.017); catalogued as rs761329600; called by muse, mutect2, varscan2
- RBPJL | c.244G>A p.G82R | Missense Mutation (SNP) | VAF 149/298 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs767768517, COSV59214043; called by muse, mutect2, varscan2
- RECK | c.563C>T p.A188V | Missense Mutation (SNP) | VAF 152/302 reads (50%) | SIFT tolerated (0.06); PolyPhen benign (0.095); catalogued as rs373443775; called by muse, mutect2, varscan2
- RFC5 | c.80G>A p.R27Q | Missense Mutation (SNP) | VAF 83/219 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs200087929, COSV57478554; called by muse, mutect2, varscan2
- RHOT2 | c.1370C>T p.T457M | Missense Mutation (SNP) | VAF 164/343 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as rs779585460; called by muse, mutect2, varscan2
- RHOXF2 | c.359G>A p.R120H | Missense Mutation (SNP) | VAF 286/558 reads (51%) | SIFT tolerated (0.12); PolyPhen benign (0.062); catalogued as rs781886657, COSV65047714, COSV65048009; called by muse, mutect2, varscan2
- RNF40 | c.692G>A p.R231Q | Missense Mutation (SNP) | VAF 171/400 reads (43%) | SIFT tolerated (0.61); PolyPhen benign (0.022); catalogued as rs186930335; called by muse, mutect2, varscan2
- RNF40 | c.1450C>T p.R484C | Missense Mutation (SNP) | VAF 125/265 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs753414503, COSV61215442; called by muse, mutect2, varscan2
- RNF43 | c.1976del p.G659Vfs*41 | Frame Shift Del (DEL) | VAF 385/542 reads (71%) | catalogued as rs755128667, COSV68457540; called by mutect2, pindel, varscan2
- ROBO4 | c.1334G>A p.R445Q | Missense Mutation (SNP) | VAF 182/378 reads (48%) | SIFT tolerated (0.47); PolyPhen benign (0.007); catalogued as rs777716177; called by muse, mutect2, varscan2
- RPS26 | c.266G>A p.R89H | Missense Mutation (SNP) | VAF 107/222 reads (48%) | SIFT tolerated (0.29); PolyPhen benign (0.067); catalogued as rs764673368; called by muse, mutect2, varscan2
- RRNAD1 | c.1325T>C p.L442P | Missense Mutation (SNP) | VAF 136/301 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.795); catalogued as rs761902145; called by muse, mutect2, varscan2
- SBF1 | c.3394C>T p.R1132C | Missense Mutation (SNP) | VAF 237/465 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs375823291; called by muse, mutect2, varscan2
- SBF1 | c.2702G>A p.R901H | Missense Mutation (SNP) | VAF 227/509 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs763212089, COSV62368870; called by muse, mutect2, varscan2
- SBNO2 | c.1949G>A p.R650H | Missense Mutation (SNP) | VAF 313/615 reads (51%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.568); catalogued as rs368375543, COSV62320156; called by muse, mutect2, varscan2
- SBSN | c.915del p.Q306Rfs*134 | Frame Shift Del (DEL) | VAF 261/678 reads (38%) | catalogued as COSV71733302; called by mutect2, pindel, varscan2
- SCAF1 | c.1034A>G p.D345G | Missense Mutation (SNP) | VAF 287/603 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.069); catalogued as rs1190076794; called by muse, mutect2, varscan2
- SCART1 | c.2359C>T p.R787C | Missense Mutation (SNP) | VAF 280/577 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV62986246; called by muse, mutect2, varscan2
- SCN3A | c.890G>A p.G297D | Missense Mutation (SNP) | VAF 156/451 reads (35%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as rs1229817884; called by muse, varscan2
- SCP2 | c.1066C>A p.P356T | Missense Mutation (SNP) | VAF 122/265 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65261377; called by mutect2, varscan2
- SCUBE2 | c.1825C>T p.R609* | Nonsense Mutation (SNP) | VAF 137/306 reads (45%) | catalogued as rs778614754, COSV58544121; called by muse, mutect2
- SEC14L1 | c.1129C>T p.R377* | Nonsense Mutation (SNP) | VAF 109/264 reads (41%) | catalogued as rs1385481222; called by muse, mutect2, varscan2
- SEC23IP | c.1015G>A p.E339K | Missense Mutation (SNP) | VAF 156/339 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); catalogued as rs370450206; called by muse, mutect2, varscan2
- SEC24B | c.1102G>A p.A368T | Missense Mutation (SNP) | VAF 164/298 reads (55%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.005); catalogued as rs762396474, COSV54506724; called by muse, mutect2, varscan2
- SELL | c.251C>T p.A84V (on ENST00000650983; = p.A71V on NM_000655.5) | Missense Mutation (SNP) | VAF 164/349 reads (47%) | SIFT deleterious (0.05); PolyPhen benign (0.031); catalogued as rs1347222080, COSV52551637; called by muse, mutect2, varscan2
- SEMA3G | c.341_344del p.T114Sfs*18 | Frame Shift Del (DEL) | VAF 135/308 reads (44%) | catalogued as rs1199597396; called by pindel, varscan2
- SEMA5A | c.1598C>T p.P533L | Missense Mutation (SNP) | VAF 115/234 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs144473454; called by muse, mutect2, varscan2
- SEPTIN4 | c.856C>T p.R286* | Nonsense Mutation (SNP) | VAF 147/309 reads (48%) | catalogued as rs199652012; called by muse, mutect2, varscan2
- SEPTIN8 | c.415C>T p.R139C | Missense Mutation (SNP) | VAF 198/439 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as rs371690570; called by muse, mutect2, varscan2
- SEZ6 | c.383C>T p.A128V | Missense Mutation (SNP) | VAF 99/458 reads (22%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0); catalogued as rs548817464, COSV57982676; called by muse, varscan2
- SGO1 | c.1564dup p.R522Kfs*29 (on ENST00000263753 / NM_001012410.5; = p.R253Kfs*29 on NM_138484.5 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 86/168 reads (51%) | catalogued as rs772386209; called by mutect2, varscan2
- SHLD1 | c.308A>G p.Y103C | Missense Mutation (SNP) | VAF 213/402 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1368912927; called by muse, mutect2, varscan2
- SIN3B | c.1607C>T p.S536L | Missense Mutation (SNP) | VAF 238/449 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.609); catalogued as rs772162952; called by muse, mutect2, varscan2
- SIPA1L3 | c.4081C>T p.R1361W | Missense Mutation (SNP) | VAF 243/550 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.711); catalogued as rs374780684; called by muse, mutect2, varscan2
- SIRPA | c.721C>T p.R241C | Missense Mutation (SNP) | VAF 226/460 reads (49%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.92); catalogued as COSV100605219; called by muse, mutect2, varscan2
- SIRPA | c.1183C>T p.R395* | Nonsense Mutation (SNP) | VAF 168/318 reads (53%) | catalogued as rs765828306; called by muse, mutect2, varscan2
- SIRT2 | c.602G>A p.R201Q | Missense Mutation (SNP) | VAF 103/221 reads (47%) | SIFT tolerated (0.08); PolyPhen benign (0.038); catalogued as rs756288624; called by muse, mutect2, varscan2
- SLC12A7 | c.473C>T p.A158V | Missense Mutation (SNP) | VAF 210/420 reads (50%) | SIFT tolerated (0.1); PolyPhen benign (0.017); catalogued as rs1380345284; called by muse, varscan2
- SLC22A2 | c.242C>T p.A81V | Missense Mutation (SNP) | VAF 242/513 reads (47%) | SIFT tolerated (0.3); PolyPhen benign (0.164); catalogued as rs771745592, COSV65266251; called by muse, mutect2, varscan2
- SLC25A47 | c.767G>A p.R256Q | Missense Mutation (SNP) | VAF 252/516 reads (49%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.557); catalogued as rs140446618; called by muse, mutect2, varscan2
- SLC27A1 | c.1520G>A p.R507H | Missense Mutation (SNP) | VAF 186/393 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs886598213, COSV53100742; called by muse, mutect2, varscan2
- SLC35B2 | c.1291_1293del p.K431del | In Frame Del (DEL) | VAF 97/308 reads (31%) | catalogued as rs752392556; called by mutect2, pindel, varscan2
- SLC38A10 | c.554G>A p.R185Q | Missense Mutation (SNP) | VAF 236/449 reads (53%) | SIFT tolerated (0.24); PolyPhen benign (0.164); catalogued as COSV99917540; called by muse, mutect2, varscan2
- SLC48A1 | c.433G>A p.D145N | Missense Mutation (SNP) | VAF 144/300 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV50410589; called by muse, mutect2, varscan2
- SLC49A3 | c.280G>A p.G94R | Missense Mutation (SNP) | VAF 148/292 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs759827121; called by muse, mutect2, varscan2
- SLC52A1 | c.1000G>A p.V334M | Missense Mutation (SNP) | VAF 163/347 reads (47%) | SIFT tolerated (0.14); PolyPhen benign (0.433); catalogued as rs150164483; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SLC6A9 | c.973G>A p.V325M (on ENST00000360584 / NM_201649.4; = p.V271M on NM_006934.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 180/363 reads (50%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); catalogued as rs200759556, COSV100746527, COSV100746583; called by muse, mutect2, varscan2
- SLIT2 | c.3641G>A p.R1214H | Missense Mutation (SNP) | VAF 177/374 reads (47%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs757958276, COSV56578826; called by muse, mutect2, varscan2
- SMC2 | c.3108G>A p.K1036= | Splice Region (SNP) | VAF 56/189 reads (30%) | catalogued as COSV99659680; called by muse, mutect2, varscan2
- SMCO4 | c.55C>T p.R19W | Missense Mutation (SNP) | VAF 204/404 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.433); catalogued as rs140592708, COSV100127888, COSV54360616; called by muse, mutect2, varscan2
- SMIM24 | c.388A>G p.M130V | Missense Mutation (SNP) | VAF 164/336 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.081); catalogued as rs868388883; called by muse, mutect2, varscan2
- SMURF1 | c.1690C>T p.R564W | Missense Mutation (SNP) | VAF 204/414 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.882); catalogued as rs1445831623; called by muse, mutect2, varscan2
- SNAPC4 | c.4097C>T p.A1366V | Missense Mutation (SNP) | VAF 242/499 reads (48%) | SIFT tolerated (0.08); PolyPhen benign (0.088); catalogued as rs752050888, COSV53737813; called by muse, mutect2, varscan2
- SNCAIP | c.2048A>G p.N683S | Missense Mutation (SNP) | VAF 195/383 reads (51%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as rs767300992; called by muse, mutect2, varscan2
- SNRNP200 | c.2858G>A p.R953Q | Missense Mutation (SNP) | VAF 360/575 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs759448209, COSV60488738; called by muse, mutect2, varscan2
- SNRNP25 | c.160C>T p.P54S (on ENST00000383018; = p.P45S on NM_024571.4) | Missense Mutation (SNP) | VAF 82/185 reads (44%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.931); catalogued as rs762660007, COSV51957790; called by muse, mutect2, varscan2
- SNX11 | c.327-1G>T p.X109_splice | Splice Site (SNP) | VAF 139/244 reads (57%) | catalogued as COSV63658520; called by muse, mutect2, varscan2
- SNX20 | c.361G>A p.A121T | Missense Mutation (SNP) | VAF 193/363 reads (53%) | SIFT deleterious (0.03); PolyPhen benign (0.09); catalogued as rs775632741, COSV100319084; called by muse, mutect2, varscan2
- SP140 | c.2015dup p.R673Efs*9 | Frame Shift Ins (INS) | VAF 92/200 reads (46%) | catalogued as rs746109620; called by mutect2, varscan2
- SPATA13 | c.146C>T p.P49L | Missense Mutation (SNP) | VAF 128/275 reads (47%) | SIFT tolerated (0.05); PolyPhen benign (0.011); catalogued as rs765118612, COSV66067959; called by muse, mutect2, varscan2
- SPATA2 | c.890C>T p.S297L | Missense Mutation (SNP) | VAF 235/507 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs746233167, COSV56866665; called by muse, mutect2, varscan2
- SPEG | c.67C>T p.P23S | Missense Mutation (SNP) | VAF 258/524 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs1054445743; called by muse, mutect2, varscan2
- SPEN | c.266G>A p.R89Q | Missense Mutation (SNP) | VAF 210/451 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs752192287; called by muse, mutect2, varscan2
- SPINT1 | c.340G>A p.A114T | Missense Mutation (SNP) | VAF 186/396 reads (47%) | SIFT tolerated (0.51); PolyPhen benign (0.015); catalogued as rs111695130; called by muse, mutect2, varscan2
- SPOCD1 | c.281C>T p.S94L | Missense Mutation (SNP) | VAF 200/418 reads (48%) | SIFT tolerated (0.54); PolyPhen benign (0.001); catalogued as rs769640684, COSV57100403; called by muse, mutect2, varscan2
- SPOUT1 | c.1055G>A p.R352H | Missense Mutation (SNP) | VAF 114/216 reads (53%) | SIFT deleterious (0.02); PolyPhen benign (0.443); catalogued as rs756502359, COSV63509214; called by muse, mutect2, varscan2
- SPTY2D1 | c.1777G>A p.D593N | Missense Mutation (SNP) | VAF 185/381 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs768279652; called by muse, mutect2, varscan2
- SRSF5 | c.779G>A p.R260Q | Missense Mutation (SNP) | VAF 120/294 reads (41%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.013); catalogued as rs191376708; called by muse, mutect2, varscan2
- SSBP1 | c.289G>A p.V97M | Missense Mutation (SNP) | VAF 157/329 reads (48%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.675); catalogued as rs148271472; called by muse, varscan2
- SSH2 | c.1276C>T p.R426* | Nonsense Mutation (SNP) | VAF 165/368 reads (45%) | catalogued as rs1171387969; called by muse, mutect2, varscan2
- STAB1 | c.5138C>T p.A1713V | Missense Mutation (SNP) | VAF 258/474 reads (54%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as rs376841854; called by muse, mutect2, varscan2
- STAB2 | c.2149C>T p.R717W | Missense Mutation (SNP) | VAF 174/354 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.745); catalogued as rs1319195464; called by muse, mutect2, varscan2
- STK10 | c.2309G>A p.R770Q | Missense Mutation (SNP) | VAF 86/193 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs766953268; called by muse, mutect2, varscan2
- STOML1 | c.664G>A p.V222M | Missense Mutation (SNP) | VAF 224/414 reads (54%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as rs776788505; called by muse, mutect2, varscan2
- STRIP1 | c.1472G>A p.R491H | Missense Mutation (SNP) | VAF 119/252 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.82); catalogued as rs146229969; called by muse, varscan2
- SUMO2 | c.272C>T p.T91M | Missense Mutation (SNP) | VAF 119/268 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.37); catalogued as rs1204753119, COSV58813600; called by muse, mutect2, varscan2
- SYTL3 | c.682C>T p.R228W | Missense Mutation (SNP) | VAF 166/344 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1270112786; called by muse, mutect2, varscan2
- TAF1 | c.2468G>A p.R823Q (on ENST00000373790 / NM_138923.4; = p.R844Q on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 179/183 reads (98%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV52115163; called by muse, mutect2, varscan2
- TAF11L2 | c.23G>A p.G8D | Missense Mutation (SNP) | VAF 117/249 reads (47%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as rs1160403496; called by muse, mutect2, varscan2
- TAF1C | c.1361del p.P454Lfs*14 | Frame Shift Del (DEL) | VAF 149/374 reads (40%) | catalogued as rs749363736; called by mutect2, pindel, varscan2
- TAF2 | c.1175G>A p.R392H | Missense Mutation (SNP) | VAF 88/190 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs773854593, COSV65418415; called by muse, mutect2, varscan2
- TAS1R1 | c.2453G>A p.R818H | Missense Mutation (SNP) | VAF 156/326 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1349457816; called by muse, varscan2
- TBC1D13 | c.655G>A p.A219T | Missense Mutation (SNP) | VAF 185/366 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1429757800; called by muse, mutect2, varscan2
- TBL3 | c.1188G>T p.K396N | Missense Mutation (SNP) | VAF 160/318 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60340596; called by muse, mutect2, varscan2
- TCAP | c.103G>A p.E35K | Missense Mutation (SNP) | VAF 142/286 reads (50%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.719); catalogued as rs779699520, COSV54094388; called by muse, mutect2, varscan2
- TDRD5 | c.35G>A p.R12Q | Missense Mutation (SNP) | VAF 144/298 reads (48%) | SIFT tolerated (0.24); PolyPhen benign (0.233); catalogued as rs779368895, COSV99677539; called by muse, mutect2, varscan2
- TEAD2 | c.1300G>A p.E434K | Missense Mutation (SNP) | VAF 131/291 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as rs556204126, COSV60545238; called by muse, mutect2, varscan2
- TEDC2 | c.1261G>A p.A421T | Missense Mutation (SNP) | VAF 174/413 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.073); catalogued as rs759305264, COSV62522828; called by muse, mutect2, varscan2
- TENM2 | c.7694C>T p.T2565M (on ENST00000518659 / NM_001122679.2; = p.T2326M on NM_001080428.3) | Missense Mutation (SNP) | VAF 239/470 reads (51%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as rs374088936; called by muse, mutect2, varscan2
- TICRR | c.5643_5644del p.P1882Ffs*69 | Frame Shift Del (DEL) | VAF 47/331 reads (14%) | catalogued as rs751002886; called by pindel, varscan2
- TJP1 | c.2050C>T p.R684C | Missense Mutation (SNP) | VAF 167/336 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs1288621536; called by muse, mutect2, varscan2
- TLE6 | c.1330C>T p.R444W (on ENST00000246112 / NM_001143986.2; = p.R321W on NM_024760.3) | Missense Mutation (SNP) | VAF 150/367 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs751705597, COSV55735559; called by muse, mutect2, varscan2
- TMC7 | c.2114G>A p.R705H | Missense Mutation (SNP) | VAF 98/212 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.026); catalogued as rs1220471909; called by muse, mutect2, varscan2
- TMEM125 | c.133G>A p.V45M | Missense Mutation (SNP) | VAF 83/464 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as rs1487856824; called by muse, mutect2, varscan2
- TMEM184A | c.1019del p.P340Rfs*15 | Frame Shift Del (DEL) | VAF 152/371 reads (41%) | catalogued as rs747152549, COSV52472232, COSV52475858; called by mutect2, pindel, varscan2
- TMEM19 | c.934G>A p.A312T | Missense Mutation (SNP) | VAF 124/276 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.938); catalogued as rs778761272, COSV56999712; called by muse, varscan2
- TMEM201 | c.538C>T p.R180C | Missense Mutation (SNP) | VAF 200/425 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs746336377; called by muse, mutect2, varscan2
- TMPRSS12 | c.795+7C>T | Splice Region (SNP) | VAF 183/395 reads (46%) | catalogued as rs777612545; called by muse, mutect2, varscan2
- TMPRSS13 | c.1485G>A p.M495I | Missense Mutation (SNP) | VAF 86/423 reads (20%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.511); catalogued as rs1183975454; called by muse, mutect2, varscan2
- TMUB2 | c.878G>A p.R293H (on ENST00000538716 / NM_001353177.2; = p.R273H on NM_024107.3 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 63/382 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as rs763787326; called by muse, mutect2, varscan2
- TNFRSF11A | c.1733G>A p.R578Q | Missense Mutation (SNP) | VAF 275/553 reads (50%) | SIFT tolerated (0.15); PolyPhen benign (0.194); catalogued as rs757983626, COSV54025565; called by muse, varscan2
- TNFRSF8 | c.778G>A p.V260M | Missense Mutation (SNP) | VAF 110/252 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs141023619; called by muse, mutect2, varscan2
- TNFSF9 | c.571G>A p.E191K | Missense Mutation (SNP) | VAF 251/502 reads (50%) | SIFT tolerated (0.6); PolyPhen possibly damaging (0.761); catalogued as COSV55537869; called by muse, mutect2, varscan2
- TNS1 | c.794G>A p.R265H | Missense Mutation (SNP) | VAF 157/362 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs762043344, COSV50698478; called by muse, mutect2, varscan2
- TPCN2 | c.1991G>A p.R664H | Missense Mutation (SNP) | VAF 135/290 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.175); catalogued as rs770687181, COSV99037211; called by muse, mutect2, varscan2
- TRGV10 | c.122C>T p.S41L | Missense Mutation (SNP) | VAF 126/294 reads (43%) | SIFT tolerated (0.21); PolyPhen benign (0.023); catalogued as rs538087143; called by muse, mutect2, varscan2
- TRIM47 | c.1699G>A p.G567S | Missense Mutation (SNP) | VAF 245/490 reads (50%) | SIFT tolerated (0.91); PolyPhen benign (0.442); catalogued as rs748329899, COSV99638512; called by muse, mutect2, varscan2
- TRIP10 | c.995del p.P332Hfs*31 | Frame Shift Del (DEL) | VAF 35/80 reads (44%) | catalogued as rs1173371682; called by mutect2, pindel, varscan2
- TRPC3 | c.2032G>A p.A678T (on ENST00000379645 / NM_001366479.2; = p.A605T on NM_003305.2) | Missense Mutation (SNP) | VAF 109/235 reads (46%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.981); catalogued as rs1446275099; called by muse, mutect2, varscan2
- TRRAP | c.3103C>T p.R1035W | Missense Mutation (SNP) | VAF 170/380 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV62841933; called by muse, varscan2
- TTC22 | c.1694G>A p.R565Q | Missense Mutation (SNP) | VAF 171/344 reads (50%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.899); catalogued as rs1162291546; called by muse, mutect2, varscan2
- TTC7A | c.2041G>A p.A681T | Missense Mutation (SNP) | VAF 338/542 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs758259662, COSV55408475; called by muse, mutect2, varscan2
- TTLL3 | c.1295G>A p.R432H | Missense Mutation (SNP) | VAF 89/209 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs540565542, COSV59613688; called by muse, mutect2, varscan2
- TTN | c.40313T>C p.L13438P (on ENST00000591111; = p.L6014P on NM_003319.4) | Missense Mutation (SNP) | VAF 211/407 reads (52%) | PolyPhen benign (0.186); catalogued as rs1033335592, COSV59976479; called by muse, mutect2, varscan2
- TTN | c.21048G>T p.E7016D (on ENST00000591111; = p.E6089D on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 168/347 reads (48%) | PolyPhen benign (0.012); catalogued as COSV100628744; called by muse, mutect2
- TTN | c.1822A>C p.T608P (on ENST00000591111; = p.T562P on NM_003319.4) | Missense Mutation (SNP) | VAF 20/195 reads (10%) | PolyPhen benign (0.006); catalogued as rs902918610; called by muse, mutect2, varscan2
- TUBB4A | c.902C>T p.A301V | Missense Mutation (SNP) | VAF 283/526 reads (54%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.043); catalogued as COSV51160341; called by muse, varscan2
- TXNDC2 | c.530G>A p.G177D (on ENST00000306084 / NM_001098529.2; = p.G110D on NM_032243.6) | Missense Mutation (SNP) | VAF 275/663 reads (41%) | SIFT tolerated (0.29); PolyPhen benign (0.038); catalogued as COSV60153537; called by muse, mutect2, varscan2
- UBA7 | c.2627G>A p.R876Q | Missense Mutation (SNP) | VAF 241/444 reads (54%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as rs199939644; called by muse, mutect2, varscan2
- UBAP1L | c.739dup p.A247Gfs*13 | Frame Shift Ins (INS) | VAF 160/389 reads (41%) | catalogued as rs753661357; called by mutect2, varscan2
- UBE2S | c.398C>T p.A133V | Missense Mutation (SNP) | VAF 184/388 reads (47%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.886); catalogued as rs1369706768, COSV99198773; called by muse, mutect2
- UBR5 | c.5927+1G>A p.X1976_splice | Splice Site (SNP) | VAF 34/239 reads (14%) | catalogued as COSV55300009; called by muse, mutect2, varscan2
- UBXN2B | c.187C>T p.R63W | Missense Mutation (SNP) | VAF 93/208 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); catalogued as rs200008585; called by muse, mutect2, varscan2
- UBXN2B | c.847C>T p.R283W | Missense Mutation (SNP) | VAF 142/285 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1345383179, COSV68308890; called by muse, mutect2, varscan2
- UNC45A | c.1237C>T p.R413W | Missense Mutation (SNP) | VAF 186/421 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs373214423; called by muse, mutect2, varscan2
- UNC5B | c.220G>A p.A74T | Missense Mutation (SNP) | VAF 144/336 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs372528064; called by muse, mutect2, varscan2
- UTP4 | c.983G>A p.R328Q | Missense Mutation (SNP) | VAF 124/268 reads (46%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.927); catalogued as rs762272300, COSV58732102; called by muse, varscan2
- UVSSA | c.1354G>A p.E452K | Missense Mutation (SNP) | VAF 213/439 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.717); catalogued as rs1232484194, COSV66230616; called by muse, mutect2, varscan2
- UXS1 | c.1247G>A p.R416Q | Missense Mutation (SNP) | VAF 290/433 reads (67%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.921); catalogued as rs768079305; called by muse, varscan2
- VANGL1 | c.557G>A p.R186H | Missense Mutation (SNP) | VAF 195/421 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs752742934, CM127310; called by muse, varscan2
- VPS9D1 | c.97del p.R33Gfs*8 | Frame Shift Del (DEL) | VAF 161/386 reads (42%) | catalogued as rs1234360395; called by mutect2, pindel, varscan2
- WFIKKN2 | c.1366A>G p.T456A | Missense Mutation (SNP) | VAF 235/509 reads (46%) | SIFT tolerated (0.75); PolyPhen benign (0.028); catalogued as rs375510528; called by muse, mutect2, varscan2
- WNK2 | c.6341G>A p.R2114H (on ENST00000297954 / NM_001282394.1; = p.R2077H on NM_006648.3) | Missense Mutation (SNP) | VAF 173/384 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.664); catalogued as rs1388947041; called by muse, mutect2, varscan2
- WNT9B | c.689C>T p.P230L | Missense Mutation (SNP) | VAF 282/578 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.463); catalogued as rs765555952, COSV99255014; called by muse, mutect2, varscan2
- XIRP1 | c.3971C>T p.P1324L | Missense Mutation (SNP) | VAF 268/542 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs769089308, COSV61137375; called by muse, mutect2, varscan2
- XXYLT1 | c.1094A>G p.Y365C | Missense Mutation (SNP) | VAF 117/495 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1377671920; called by muse, mutect2, varscan2
- ZACN | c.756del p.L253Cfs*10 | Frame Shift Del (DEL) | VAF 228/565 reads (40%) | catalogued as rs746294699; called by mutect2, pindel, varscan2
- ZAN | c.5890G>A p.A1964T | Missense Mutation (SNP) | VAF 168/371 reads (45%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs771814609; called by muse, mutect2, varscan2
- ZBTB44 | c.1036G>A p.V346I | Missense Mutation (SNP) | VAF 94/211 reads (45%) | SIFT tolerated (0.14); PolyPhen benign (0.01); catalogued as rs1028585105, COSV63537729; called by muse, mutect2, varscan2
- ZBTB8B | c.1138C>T p.R380* | Nonsense Mutation (SNP) | VAF 191/402 reads (48%) | catalogued as rs766409585; called by muse, mutect2, varscan2
- ZEB1 | c.2317G>A p.A773T | Missense Mutation (SNP) | VAF 162/365 reads (44%) | SIFT tolerated (0.36); PolyPhen benign (0.009); catalogued as rs754135071, COSV58042268, COSV58050747; called by muse, mutect2, varscan2
- ZFHX3 | c.10215del p.A3407Lfs*78 | Frame Shift Del (DEL) | VAF 166/484 reads (34%) | catalogued as rs762108866; called by pindel, varscan2
- ZFP92 | c.953G>A p.R318Q | Missense Mutation (SNP) | VAF 333/335 reads (99%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.791); catalogued as rs1556975095; called by muse, varscan2
- ZMYM3 | c.647del p.P216Lfs*11 | Frame Shift Del (DEL) | VAF 49/232 reads (21%) | catalogued as COSV58736302; called by mutect2, pindel, varscan2
- ZNF219 | c.2011C>T p.R671C | Missense Mutation (SNP) | VAF 287/577 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.543); catalogued as rs1290601756; called by muse, mutect2, varscan2
- ZNF224 | c.1100C>T p.T367M | Missense Mutation (SNP) | VAF 218/476 reads (46%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.903); catalogued as rs763968126; called by muse, mutect2
- ZNF236 | c.181C>T p.R61* | Nonsense Mutation (SNP) | VAF 129/247 reads (52%) | catalogued as rs1191784802; called by muse, mutect2, varscan2
- ZNF281 | c.1646G>A p.S549N | Missense Mutation (SNP) | VAF 14/460 reads (3%) | SIFT tolerated (0.44); PolyPhen benign (0.052); catalogued as rs1171668754; called by muse, mutect2
- ZNF317 | c.1579del p.E527Rfs*15 | Frame Shift Del (DEL) | VAF 231/558 reads (41%) | catalogued as COSV56110960; called by mutect2, pindel, varscan2
- ZNF507 | c.1189G>A p.V397M | Missense Mutation (SNP) | VAF 46/402 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1189590570, COSV100321471; called by muse, mutect2, varscan2
- ZNF518A | c.57del p.D20Ifs*4 | Frame Shift Del (DEL) | VAF 76/202 reads (38%) | catalogued as COSV60151560; called by mutect2, varscan2
- ZNF521 | c.2684A>G p.Y895C | Missense Mutation (SNP) | VAF 165/326 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV64130931; called by muse, mutect2, varscan2
- ZNF524 | c.214del p.V72* | Frame Shift Del (DEL) | VAF 219/545 reads (40%) | catalogued as rs1249713061; called by mutect2, pindel, varscan2
- ZNF574 | c.418C>A p.L140I | Missense Mutation (SNP) | VAF 232/497 reads (47%) | SIFT tolerated (0.29); PolyPhen benign (0.012); catalogued as rs759453967; called by muse, mutect2, varscan2
- ZNF626 | c.215C>T p.A72V | Missense Mutation (SNP) | VAF 93/206 reads (45%) | SIFT tolerated (0.06); PolyPhen benign (0.046); catalogued as COSV99391808; called by muse, mutect2, varscan2
- ZNF728 | c.20G>A p.R7Q | Missense Mutation (SNP) | VAF 102/198 reads (52%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as rs530488414, COSV74099329; called by muse, mutect2, varscan2
- ZNF775 | c.175C>T p.R59W | Missense Mutation (SNP) | VAF 285/579 reads (49%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs1241882894; called by muse, mutect2, varscan2
- ABCB11 | c.343A>G p.T115A | Missense Mutation (SNP) | VAF 70/575 reads (12%) | SIFT tolerated (0.42); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ABCB9 | c.1682del p.G561Afs*21 (on ENST00000280560 / NM_019625.4; = p.G518Afs*21 on NM_019624.3) | Frame Shift Del (DEL) | VAF 185/524 reads (35%) | called by pindel, varscan2
- ABCC8 | c.3065dup p.H1023Afs*91 | Frame Shift Ins (INS) | VAF 192/499 reads (38%) | called by mutect2, pindel, varscan2
- AC006059.2 | c.619G>A p.A207T | Missense Mutation (SNP) | VAF 152/375 reads (41%) | SIFT tolerated (0.12); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- AC090517.4 | c.818C>T p.T273I | Missense Mutation (SNP) | VAF 96/215 reads (45%) | SIFT tolerated (0.08); PolyPhen benign (0.038); called by muse, varscan2
- ACACA | c.1345G>A p.A449T | Missense Mutation (SNP) | VAF 187/378 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ACLY | c.1354A>G p.R452G | Missense Mutation (SNP) | VAF 108/238 reads (45%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- ADA | c.416A>T p.E139V | Missense Mutation (SNP) | VAF 198/407 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.489); called by muse, varscan2
- ADAM20 | c.2117del p.L706Yfs*? | Frame Shift Del (DEL) | VAF 146/294 reads (50%) | called by mutect2, varscan2
- ADAMTS6 | c.794A>C p.Y265S | Missense Mutation (SNP) | VAF 34/302 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); called by muse, mutect2, varscan2
- ADAMTSL1 | c.1214A>G p.E405G | Missense Mutation (SNP) | VAF 31/448 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ADAMTSL1 | c.2038C>T p.L680F | Missense Mutation (SNP) | VAF 72/280 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- ADAT1 | c.607A>G p.T203A | Missense Mutation (SNP) | VAF 184/388 reads (47%) | SIFT tolerated (0.78); PolyPhen benign (0.003); called by mutect2, varscan2
- ADCY7 | c.432G>A p.M144I | Missense Mutation (SNP) | VAF 218/467 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.24); called by muse, mutect2, varscan2
- ADGRA2 | c.2762G>T p.W921L | Missense Mutation (SNP) | VAF 114/242 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.572); called by mutect2, varscan2
- ADGRB1 | c.1489C>T p.P497S | Missense Mutation (SNP) | VAF 75/454 reads (17%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.713); called by muse, mutect2, varscan2
- ADGRV1 | c.16688A>G p.E5563G | Missense Mutation (SNP) | VAF 147/337 reads (44%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- AFF1 | c.1476C>G p.S492R | Missense Mutation (SNP) | VAF 100/237 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- AGRN | c.5233del p.R1745Vfs*15 | Frame Shift Del (DEL) | VAF 199/459 reads (43%) | called by mutect2, pindel, varscan2
- AGTPBP1 | c.1277del p.F426Sfs*13 (on ENST00000357081 / NM_001330701.2; = p.F386Sfs*13 on NM_015239.2) | Frame Shift Del (DEL) | VAF 120/294 reads (41%) | called by mutect2, pindel, varscan2
- AHNAK | c.13635G>T p.E4545D | Missense Mutation (SNP) | VAF 187/353 reads (53%) | SIFT deleterious (0.03); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- AIP | c.820G>A p.A274T | Missense Mutation (SNP) | VAF 173/386 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- AK4 | c.609G>A p.W203* | Nonsense Mutation (SNP) | VAF 39/301 reads (13%) | called by muse, mutect2, varscan2
- AKNA | c.3969del p.G1324Dfs*72 | Frame Shift Del (DEL) | VAF 220/561 reads (39%) | called by mutect2, pindel, varscan2
- ALOX12B | c.620C>T p.T207M | Missense Mutation (SNP) | VAF 148/272 reads (54%) | SIFT tolerated (0.06); PolyPhen benign (0.18); called by muse, mutect2, varscan2
- ANKRD29 | c.677T>A p.V226D | Missense Mutation (SNP) | VAF 153/299 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ANO8 | c.524A>G p.N175S | Missense Mutation (SNP) | VAF 136/271 reads (50%) | SIFT tolerated (0.16); PolyPhen benign (0.168); called by muse, mutect2, varscan2
- AP4B1 | c.802del p.H268Tfs*15 | Frame Shift Del (DEL) | VAF 202/536 reads (38%) | called by mutect2, pindel, varscan2
- APP | c.470C>T p.T157I | Missense Mutation (SNP) | VAF 96/227 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.251); called by muse, mutect2, varscan2
- ARAF | c.23del p.P8Lfs*26 | Frame Shift Del (DEL) | VAF 199/272 reads (73%) | called by mutect2, pindel, varscan2
- ARHGEF1 | c.1030del p.L344Wfs*12 | Frame Shift Del (DEL) | VAF 185/435 reads (43%) | called by mutect2, pindel, varscan2
- ARID1A | c.4555del p.Q1519Rfs*8 | Frame Shift Del (DEL) | VAF 172/500 reads (34%) | called by pindel, varscan2
- ARID5B | c.307A>T p.I103F | Missense Mutation (SNP) | VAF 113/236 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.548); called by muse, mutect2, varscan2
- ARID5B | c.1513G>A p.A505T | Missense Mutation (SNP) | VAF 222/435 reads (51%) | SIFT tolerated (0.48); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ARMC10 | c.787T>C p.S263P | Missense Mutation (SNP) | VAF 103/271 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- ASAP3 | c.2578dup p.A860Gfs*5 | Frame Shift Ins (INS) | VAF 156/334 reads (47%) | called by mutect2, varscan2
- ASCC3 | c.1601T>C p.V534A | Missense Mutation (SNP) | VAF 121/226 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- ASTN2 | c.2365A>G p.N789D (on ENST00000313400 / NM_001365069.1; = p.N738D on NM_014010.5) | Missense Mutation (SNP) | VAF 156/315 reads (50%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.626); called by muse, mutect2, varscan2
- ATG2B | c.4973A>G p.Q1658R | Missense Mutation (SNP) | VAF 145/300 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.165); called by muse, mutect2, varscan2
- ATOH1 | c.1021T>C p.F341L | Missense Mutation (SNP) | VAF 161/328 reads (49%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- ATP13A2 | c.1424C>T p.A475V | Missense Mutation (SNP) | VAF 43/405 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ATP1A3 | c.1998C>A p.C666* (on ENST00000545399 / NM_001256214.2; = p.C653* on NM_152296.5) | Nonsense Mutation (SNP) | VAF 144/276 reads (52%) | called by muse, mutect2, varscan2
- ATP2A1 | c.1941G>T p.E647D | Missense Mutation (SNP) | VAF 215/458 reads (47%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ATP6V1B2 | c.1138G>A p.D380N | Missense Mutation (SNP) | VAF 112/271 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.871); called by muse, varscan2
- ATXN1 | c.438G>T p.Q146H | Missense Mutation (SNP) | VAF 296/832 reads (36%) | SIFT tolerated (0.77); PolyPhen possibly damaging (0.656); called by muse, mutect2
- ATXN7 | c.681_682del p.K228Tfs*17 | Frame Shift Del (DEL) | VAF 157/480 reads (33%) | called by pindel, varscan2
- ATXN7L2 | c.1995G>T p.E665D | Missense Mutation (SNP) | VAF 252/500 reads (50%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- B2M | c.276del p.T93Lfs*10 | Frame Shift Del (DEL) | VAF 227/571 reads (40%) | called by mutect2, pindel, varscan2
- B4GALNT4 | c.1240del p.D414Mfs*81 | Frame Shift Del (DEL) | VAF 154/350 reads (44%) | called by mutect2, pindel, varscan2
- BAHCC1 | c.7414C>T p.P2472S | Missense Mutation (SNP) | VAF 200/414 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- BARD1 | c.1447C>T p.H483Y | Missense Mutation (SNP) | VAF 192/390 reads (49%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.871); called by muse, mutect2, varscan2
- BCL9L | c.3986T>C p.I1329T | Missense Mutation (SNP) | VAF 58/577 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.672); called by muse, mutect2, varscan2
- BIRC2 | c.134G>A p.C45Y | Missense Mutation (SNP) | VAF 164/310 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- BRCA2 | c.9333G>T p.E3111D | Missense Mutation (SNP) | VAF 147/291 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- BRD3 | c.449del p.P150Lfs*93 | Frame Shift Del (DEL) | VAF 182/447 reads (41%) | called by mutect2, pindel, varscan2
- BRPF3 | c.3241T>C p.W1081R | Missense Mutation (SNP) | VAF 214/632 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- BTNL9 | c.1013A>G p.H338R | Missense Mutation (SNP) | VAF 186/371 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.566); called by muse, mutect2, varscan2
- C1QTNF9 | c.769G>A p.V257I | Missense Mutation (SNP) | VAF 74/385 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.344); called by muse, mutect2, varscan2
- C2orf78 | c.2672A>G p.E891G | Missense Mutation (SNP) | VAF 37/544 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- C6orf132 | c.350G>A p.G117D | Missense Mutation (SNP) | VAF 330/512 reads (64%) | SIFT deleterious (0); called by muse, mutect2, varscan2
- C8orf82 | c.610A>G p.M204V | Missense Mutation (SNP) | VAF 70/407 reads (17%) | SIFT tolerated (0.35); PolyPhen benign (0.017); called by muse, varscan2
- CACHD1 | c.2836_2837del p.L946Cfs*22 | Frame Shift Del (DEL) | VAF 120/348 reads (34%) | called by pindel, varscan2
- CAD | c.3718C>T p.R1240W | Missense Mutation (SNP) | VAF 175/543 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); called by muse, mutect2, varscan2
- CADM2 | c.464C>T p.A155V (on ENST00000407528 / NM_001167674.2; = p.A157V on NM_153184.4) | Missense Mutation (SNP) | VAF 124/273 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CAMK2A | c.320A>G p.Y107C | Missense Mutation (SNP) | VAF 182/351 reads (52%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CAMSAP1 | c.1078C>T p.P360S | Missense Mutation (SNP) | VAF 19/409 reads (5%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.981); called by muse, mutect2
- CAPN12 | c.1217del p.G406Afs*33 | Frame Shift Del (DEL) | VAF 157/334 reads (47%) | called by mutect2, varscan2
- CAPN9 | c.1273-1G>A p.X425_splice | Splice Site (SNP) | VAF 114/238 reads (48%) | called by muse, mutect2, varscan2
- CAPZB | c.148G>A p.A50T | Missense Mutation (SNP) | VAF 143/322 reads (44%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CARD11 | c.418C>T p.Q140* | Nonsense Mutation (SNP) | VAF 68/379 reads (18%) | called by muse, mutect2, varscan2
- CARD9 | c.1585G>A p.D529N | Missense Mutation (SNP) | VAF 170/392 reads (43%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.629); called by muse, varscan2
- CASS4 | c.1764del p.F588Lfs*13 | Frame Shift Del (DEL) | VAF 153/381 reads (40%) | called by mutect2, pindel, varscan2
- CCDC168 | c.16977G>T p.E5659D | Missense Mutation (SNP) | VAF 189/413 reads (46%) | SIFT tolerated (0.13); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- CCDC3 | c.193C>T p.Q65* | Nonsense Mutation (SNP) | VAF 248/494 reads (50%) | called by muse, varscan2
- CCDC61 | c.677T>A p.L226Q | Missense Mutation (SNP) | VAF 19/614 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); called by muse, mutect2
- CD28 | c.19G>A p.A7T | Missense Mutation (SNP) | VAF 59/341 reads (17%) | SIFT tolerated (0.2); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- CDAN1 | c.418del p.V140Sfs*42 | Frame Shift Del (DEL) | VAF 192/488 reads (39%) | called by mutect2, pindel, varscan2
- CDHR1 | c.2236C>A p.P746T | Missense Mutation (SNP) | VAF 245/515 reads (48%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.276); called by muse, mutect2, varscan2
- CDK4 | c.114_115del p.R38Sfs*18 | Frame Shift Del (DEL) | VAF 164/424 reads (39%) | called by pindel, varscan2
- CELA3A | c.472T>C p.Y158H | Missense Mutation (SNP) | VAF 82/444 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CELSR1 | c.4805del p.G1602Vfs*104 | Frame Shift Del (DEL) | VAF 169/437 reads (39%) | called by mutect2, pindel, varscan2
- CELSR2 | c.8508A>C p.K2836N | Missense Mutation (SNP) | VAF 95/317 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- CEP95 | c.473G>T p.R158M | Missense Mutation (SNP) | VAF 88/180 reads (49%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- CFAP54 | c.7931del p.N2644Mfs*7 | Frame Shift Del (DEL) | VAF 107/267 reads (40%) | called by mutect2, pindel, varscan2
- CFAP99 | c.468G>A p.W156* | Nonsense Mutation (SNP) | VAF 109/225 reads (48%) | called by muse, mutect2, varscan2
- CGB2 | c.328C>A p.L110I | Missense Mutation (SNP) | VAF 54/594 reads (9%) | SIFT tolerated (0.42); PolyPhen benign (0.235); called by muse, mutect2, varscan2
- CHD8 | c.7567A>T p.T2523S (on ENST00000646647 / NM_001170629.2; = p.T2244S on NM_020920.4) | Missense Mutation (SNP) | VAF 226/449 reads (50%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- CHP2 | c.386G>A p.G129E | Missense Mutation (SNP) | VAF 159/313 reads (51%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.771); called by muse, mutect2, varscan2
- CHTF18 | c.2198T>C p.M733T | Missense Mutation (SNP) | VAF 49/394 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CIC | c.94C>T p.R32* | Nonsense Mutation (SNP) | VAF 106/413 reads (26%) | called by muse, mutect2, varscan2
- CIC | c.1258del p.Q420Sfs*55 | Frame Shift Del (DEL) | VAF 225/553 reads (41%) | called by mutect2, pindel, varscan2
- CIC | c.1507C>T p.R503C | Missense Mutation (SNP) | VAF 227/455 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CKAP5 | c.2276A>G p.N759S | Missense Mutation (SNP) | VAF 13/338 reads (4%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.446); called by muse, mutect2
- CLIC1 | c.277T>C p.Y93H | Missense Mutation (SNP) | VAF 72/510 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- CLIC3 | c.124A>G p.T42A | Missense Mutation (SNP) | VAF 196/430 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CLPB | c.253G>A p.A85T | Missense Mutation (SNP) | VAF 255/526 reads (48%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CLSTN3 | c.37_38del p.L13Afs*7 | Frame Shift Del (DEL) | VAF 140/494 reads (28%) | called by pindel, varscan2
- CNNM2 | c.1897G>A p.A633T | Missense Mutation (SNP) | VAF 102/225 reads (45%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.488); called by muse, varscan2
- CNOT3 | c.781C>A p.P261T | Missense Mutation (SNP) | VAF 197/419 reads (47%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CNTLN | c.4162del p.I1388* | Frame Shift Del (DEL) | VAF 47/149 reads (32%) | called by mutect2, pindel, varscan2
- CNTNAP5 | c.1718G>A p.S573N | Missense Mutation (SNP) | VAF 159/456 reads (35%) | SIFT deleterious (0.05); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- COG5 | c.494del p.G165Efs*5 | Frame Shift Del (DEL) | VAF 99/262 reads (38%) | called by mutect2, pindel, varscan2
- COL19A1 | c.761A>G p.D254G | Missense Mutation (SNP) | VAF 93/200 reads (47%) | SIFT tolerated (0.13); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- COL6A5 | c.1031T>G p.L344R | Missense Mutation (SNP) | VAF 140/320 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- COX18 | c.664G>A p.D222N | Missense Mutation (SNP) | VAF 97/196 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CRACR2A | c.1268G>T p.R423M | Missense Mutation (SNP) | VAF 68/223 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.847); called by muse, mutect2, varscan2
- CRYBG2 | c.1300G>A p.G434R | Missense Mutation (SNP) | VAF 65/472 reads (14%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.123); called by muse, mutect2, varscan2
- CRYZ | c.448G>T p.E150* | Nonsense Mutation (SNP) | VAF 125/267 reads (47%) | called by muse, mutect2, varscan2
- CSPP1 | c.3314A>G p.D1105G (on ENST00000676605; = p.D1064G on NM_024790.6) | Missense Mutation (SNP) | VAF 102/198 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); called by muse, varscan2
- CTAGE6 | c.794A>G p.H265R | Missense Mutation (SNP) | VAF 126/529 reads (24%) | SIFT tolerated (0.3); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CTNND2 | c.3166A>G p.T1056A | Missense Mutation (SNP) | VAF 165/351 reads (47%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- CUL2 | c.2071C>T p.R691* | Nonsense Mutation (SNP) | VAF 97/218 reads (44%) | called by muse, mutect2, varscan2
- CUL3 | c.268C>T p.R90* | Nonsense Mutation (SNP) | VAF 90/160 reads (56%) | called by muse, mutect2, varscan2
- CYGB | c.334G>A p.A112T | Missense Mutation (SNP) | VAF 16/428 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.031); called by muse, mutect2
- CYP26C1 | c.142C>T p.P48S | Missense Mutation (SNP) | VAF 17/569 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CYP2F1 | c.81G>T p.K27N | Missense Mutation (SNP) | VAF 189/402 reads (47%) | SIFT tolerated (0.05); PolyPhen benign (0.346); called by muse, mutect2, varscan2
- DBN1 | c.671G>A p.R224H | Missense Mutation (SNP) | VAF 17/486 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- DDX24 | c.516G>T p.K172N | Missense Mutation (SNP) | VAF 260/557 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DENND3 | c.464T>C p.I155T | Missense Mutation (SNP) | VAF 134/322 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.669); called by muse, mutect2
- DENND4A | c.1664T>C p.L555S | Missense Mutation (SNP) | VAF 152/358 reads (42%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.856); called by muse, mutect2, varscan2
- DGKI | c.2430C>T p.D810= | Splice Region (SNP) | VAF 144/298 reads (48%) | called by muse, mutect2, varscan2
- DIP2C | c.3107del p.P1036Qfs*3 | Frame Shift Del (DEL) | VAF 116/286 reads (41%) | called by mutect2, pindel, varscan2
- DIP2C | c.1009C>A p.L337M | Missense Mutation (SNP) | VAF 209/412 reads (51%) | SIFT tolerated (0.05); PolyPhen benign (0.387); called by muse, mutect2, varscan2
- DMWD | c.1827_1829del p.L610del | In Frame Del (DEL) | VAF 185/406 reads (46%) | called by pindel, varscan2
- DNAH7 | c.472_475del p.E158Kfs*4 | Frame Shift Del (DEL) | VAF 49/274 reads (18%) | called by mutect2, pindel, varscan2
- DNMT3B | c.1787T>C p.I596T | Missense Mutation (SNP) | VAF 164/311 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DONSON | c.487C>T p.L163F | Missense Mutation (SNP) | VAF 185/392 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- DRD5 | c.1427T>C p.F476S | Missense Mutation (SNP) | VAF 84/189 reads (44%) | SIFT tolerated (0.22); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- DRG1 | c.257G>T p.G86V | Missense Mutation (SNP) | VAF 180/380 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.756); called by muse, mutect2, varscan2
- DRGX | c.695G>A p.S232N | Missense Mutation (SNP) | VAF 276/511 reads (54%) | SIFT tolerated (0.11); PolyPhen benign (0); called by muse, mutect2, varscan2
- DST | c.7763_7764dup p.D2589Mfs*21 | Frame Shift Ins (INS) | VAF 106/242 reads (44%) | called by mutect2, varscan2
- DUSP6 | c.983C>T p.S328F | Missense Mutation (SNP) | VAF 193/419 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- DYM | c.1262del p.N421Ifs*10 | Frame Shift Del (DEL) | VAF 91/200 reads (46%) | called by mutect2, varscan2
- DYNC1LI2 | c.994C>A p.P332T | Missense Mutation (SNP) | VAF 123/273 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.297); called by muse, mutect2, varscan2
- DYNC2I1 | c.2777dup p.L926Ffs*85 | Frame Shift Ins (INS) | VAF 71/162 reads (44%) | called by mutect2, pindel, varscan2
- E4F1 | c.535C>T p.Q179* | Nonsense Mutation (SNP) | VAF 201/462 reads (44%) | called by muse, mutect2, varscan2
- EBF1 | c.1714T>C p.C572R | Missense Mutation (SNP) | VAF 159/329 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.62); called by muse, mutect2, varscan2
- EBF4 | c.768del p.C257Afs*63 (on ENST00000609451; = p.C253Afs*63 on NM_001110514.1) | Frame Shift Del (DEL) | VAF 195/454 reads (43%) | called by mutect2, pindel, varscan2
- ECM1 | c.506del p.P169Lfs*9 | Frame Shift Del (DEL) | VAF 211/543 reads (39%) | called by mutect2, pindel, varscan2
- ECRG4 | c.188G>A p.G63D | Missense Mutation (SNP) | VAF 160/519 reads (31%) | SIFT tolerated (0.14); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- EED | c.862C>T p.P288S | Missense Mutation (SNP) | VAF 80/179 reads (45%) | SIFT tolerated (0.08); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- EGR3 | c.691A>G p.I231V | Missense Mutation (SNP) | VAF 118/534 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); called by muse, mutect2, varscan2
- EHBP1L1 | c.1616G>A p.S539N | Missense Mutation (SNP) | VAF 110/593 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.321); called by muse, mutect2
- EIF3I | c.88A>T p.K30* | Nonsense Mutation (SNP) | VAF 14/248 reads (6%) | called by muse, mutect2
- EIF3J | c.275A>G p.Q92R | Missense Mutation (SNP) | VAF 66/135 reads (49%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- EIF4G3 | c.4097A>G p.Q1366R | Missense Mutation (SNP) | VAF 75/180 reads (42%) | SIFT tolerated (0.23); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ELF1 | c.1483_1485del p.P495del | In Frame Del (DEL) | VAF 224/496 reads (45%) | called by pindel, varscan2
- ELOA3 | c.787C>T p.P263S | Missense Mutation (SNP) | VAF 118/776 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.387); called by muse, mutect2, varscan2
- EML5 | c.5722G>A p.D1908N (on ENST00000380664; = p.D1916N on NM_183387.3) | Missense Mutation (SNP) | VAF 135/265 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ENPP5 | c.973C>T p.H325Y | Missense Mutation (SNP) | VAF 242/386 reads (63%) | SIFT tolerated (0.42); PolyPhen benign (0); called by muse, mutect2, varscan2
- ERBB3 | c.434G>A p.G145E | Missense Mutation (SNP) | VAF 69/240 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FASN | c.3358A>G p.T1120A | Missense Mutation (SNP) | VAF 241/487 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.068); called by muse, mutect2, varscan2
802 further variants in this file (368 protein-altering or splice-affecting, 377 silent, 57 other) are not listed here.
